Somatic mutation profile of tumor specimen TCGA-G4-6309-01A (aliquot TCGA-G4-6309-01A-21D-1835-10) from TCGA case TCGA-G4-6309, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Sigmoid colon; AJCC pathologic stage: Stage IIIB; Age at diagnosis: 40.3 years (14,729 days).
Specimen TCGA-G4-6309-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 74ec0be0-4a96-455c-87f5-6fb4c46ac2b0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-G4-6309-10A (Blood Derived Normal), aliquot TCGA-G4-6309-10A-01D-1835-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9a47046c-ad70-4826-8450-b72fd8a69ab6

The open-access MAF lists 947 somatic variants for this specimen: 744 protein-altering or splice-affecting, 195 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 507, Silent 195, Frame Shift Del 131, Frame Shift Ins 55, Nonsense Mutation 29, In Frame Del 10, Splice Region 7, Splice Site 5, Intron 3, 3'UTR 2, RNA 1, 5'UTR 1.

Variants (750 of 947; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCA4 | c.4195G>A p.E1399K | Missense Mutation (SNP) | VAF 25/76 reads (33%) | SIFT tolerated (0.79); PolyPhen possibly damaging (0.559); catalogued as rs62642573, CM003380, CM159384, COSV64675467; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ACADVL | c.1316del p.G439Vfs*5 | Frame Shift Del (DEL) | VAF 10/31 reads (32%) | catalogued as rs748077880; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- AGXT | c.33dup p.K12Qfs*156 | Frame Shift Ins (INS) | VAF 14/47 reads (30%) | catalogued as rs180177201; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- AP1S1 | c.364del p.D122Mfs*11 | Frame Shift Del (DEL) | VAF 46/56 reads (82%) | catalogued as rs767358930; ClinVar: likely pathogenic; called by mutect2, varscan2
- AP5Z1 | c.721C>T p.Q241* | Nonsense Mutation (SNP) | VAF 12/39 reads (31%) | catalogued as rs751778396, COSV62244041; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- APC | c.1660C>T p.R554* | Nonsense Mutation (SNP) | VAF 78/204 reads (38%) | catalogued as rs137854573, CM920034, COSV57321615; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ATP6V1B1 | c.1155del p.I386Sfs*10 | Frame Shift Del (DEL) | VAF 27/73 reads (37%) | catalogued as rs781969081; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- B4GALNT1 | c.263dup p.L89Pfs*13 | Frame Shift Ins (INS) | VAF 11/24 reads (46%) | catalogued as rs745744124; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- DTD2 | c.16C>T p.R6W | Missense Mutation (SNP) | VAF 6/45 reads (13%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen benign (0.425); catalogued as rs17097904; called by mutect2, varscan2
- FLCN | c.1285del p.H429Tfs*39 | Frame Shift Del (DEL) | VAF 10/18 reads (56%) | catalogued as rs80338682, CD023282, CM082680; ClinVar: pathogenic; called by mutect2, varscan2
- FZD6 | c.286C>T p.R96C | Missense Mutation (SNP) | VAF 38/83 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs981045005, CM132595, COSV100708516; ClinVar: uncertain significance / pathogenic; called by muse, mutect2, varscan2
- ITPR1 | c.805C>T p.R269W | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs886039392, COSV57006244; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- KCNQ3 | c.1599del p.K533Nfs*6 | Frame Shift Del (DEL) | VAF 14/27 reads (52%) | catalogued as rs762289015, COSV101196388; ClinVar: uncertain significance / pathogenic; called by mutect2, varscan2
- LMX1B | c.668G>A p.R223Q | Missense Mutation (SNP) | VAF 38/95 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs121909491, CM981214, COSV62739259; ClinVar: pathogenic; called by muse, mutect2, varscan2
- MAP2K1 | c.167A>C p.Q56P | Missense Mutation (SNP) | VAF 10/42 reads (24%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen benign (0.303); catalogued as rs1057519729, COSV61068787; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2
- MYO7A | c.397dup p.H133Pfs*7 | Frame Shift Ins (INS) | VAF 17/36 reads (47%) | catalogued as rs111033187; ClinVar: likely pathogenic; called by mutect2, varscan2
- PIK3R1 | c.1746-2A>G p.X582_splice (on ENST00000521381 / NM_181523.3; = p.X312_splice on NM_181504.4) | Splice Site (SNP) | VAF 54/142 reads (38%) | hotspot (GDC flag); catalogued as COSV57125460, COSV57131831, COSV57142185; called by muse, mutect2
- PTEN | c.800del p.K267Rfs*9 | Frame Shift Del (DEL) | VAF 22/79 reads (28%) | catalogued as rs121913289; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- AAMP | c.44del p.P15Hfs*5 | Frame Shift Del (DEL) | VAF 27/86 reads (31%) | catalogued as rs751284215; called by mutect2, pindel, varscan2
- ABCA2 | c.906G>T p.Q302H (on ENST00000614293; = p.Q272H on NM_001606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 27/72 reads (38%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.382); catalogued as rs1353087299, COSV55807383; called by muse, mutect2, varscan2
- ABCB1 | c.1972T>C p.S658P | Missense Mutation (SNP) | VAF 25/113 reads (22%) | SIFT tolerated (0.19); PolyPhen benign (0.212); catalogued as COSV55964866; called by muse, mutect2, varscan2
- ABCC5 | c.1381T>C p.S461P | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.535); catalogued as COSV99657730; called by muse, mutect2, varscan2
- ABCE1 | c.97C>T p.R33* | Nonsense Mutation (SNP) | VAF 18/36 reads (50%) | catalogued as COSV56846807; called by muse, mutect2, varscan2
- ABHD4 | c.553C>T p.R185C | Missense Mutation (SNP) | VAF 15/81 reads (19%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.935); catalogued as rs752463205, COSV53529501; called by muse, mutect2, varscan2
- ABRAXAS1 | c.775G>T p.G259* | Nonsense Mutation (SNP) | VAF 49/149 reads (33%) | catalogued as COSV55030635; called by muse, mutect2, varscan2
- ABTB2 | c.2104G>T p.G702C | Missense Mutation (SNP) | VAF 14/32 reads (44%) | SIFT tolerated (0.11); PolyPhen benign (0.235); catalogued as COSV54396608; called by muse, mutect2, varscan2
- ADAMTS9 | c.5428C>T p.R1810C | Missense Mutation (SNP) | VAF 28/78 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as rs577267039, COSV55791855; called by muse, mutect2, varscan2
- ADAMTSL2 | c.2848dup p.H950Pfs*13 | Frame Shift Ins (INS) | VAF 15/40 reads (38%) | catalogued as rs1022557002; called by mutect2, varscan2
- ADGRA1 | c.769C>T p.R257C | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as rs769465519, COSV66927765; called by muse, mutect2, varscan2
- ADRA2A | c.124C>A p.P42T | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs1241405492, COSV99701845; called by muse, mutect2
- AGAP2 | c.1636G>A p.E546K (on ENST00000547588 / NM_001122772.2; = p.E210K on NM_014770.4) | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99224426; called by muse, mutect2, varscan2
- AGBL1 | c.938A>G p.K313R | Missense Mutation (SNP) | VAF 19/44 reads (43%) | SIFT tolerated (0.17); PolyPhen benign (0.018); catalogued as COSV66874786; called by muse, mutect2, varscan2
- AGBL5 | c.616G>A p.D206N | Missense Mutation (SNP) | VAF 25/65 reads (38%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV59938633; called by muse, mutect2, varscan2
- AKAP9 | c.116del p.K39Rfs*17 | Frame Shift Del (DEL) | VAF 19/36 reads (53%) | catalogued as COSV62339755; called by mutect2, varscan2
- AL645922.1 | c.1675G>A p.A559T | Missense Mutation (SNP) | VAF 15/32 reads (47%) | SIFT tolerated (0.42); PolyPhen benign (0.161); catalogued as COSV54962839; called by muse, mutect2, varscan2
- ALDH1A3 | c.849del p.K284Rfs*83 | Frame Shift Del (DEL) | VAF 36/76 reads (47%) | catalogued as rs758955164; called by mutect2, varscan2
- ALDH3A1 | c.419C>T p.S140L | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs755608749, COSV56735616; called by muse, mutect2, varscan2
- ALDH6A1 | c.480G>T p.M160I | Missense Mutation (SNP) | VAF 29/74 reads (39%) | SIFT tolerated (0.3); PolyPhen benign (0.033); catalogued as COSV63247459; called by muse, mutect2, varscan2
- ALPK2 | c.1568del p.K523Rfs*15 | Frame Shift Del (DEL) | VAF 13/51 reads (25%) | catalogued as rs1341338515; called by mutect2, pindel, varscan2
- AMHR2 | c.1388G>A p.R463H | Missense Mutation (SNP) | VAF 30/84 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs765635891, COSV57685707; called by muse, mutect2, varscan2
- AMIGO1 | c.121G>A p.A41T | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV63990626; called by muse, mutect2, varscan2
- ANKRD46 | c.122G>A p.R41H | Missense Mutation (SNP) | VAF 34/95 reads (36%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.595); catalogued as rs765571492, COSV59516178; called by muse, mutect2, varscan2
- ANXA11 | c.137C>T p.A46V | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT deleterious (0.03); PolyPhen benign (0.015); catalogued as rs762084152, COSV55418916; called by muse, mutect2, varscan2
- ANXA7 | c.1375G>A p.A459T (on ENST00000372919 / NM_001320880.2; = p.A437T on NM_001156.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 28/65 reads (43%) | SIFT tolerated (0.57); PolyPhen benign (0.022); catalogued as rs146521289; called by muse, mutect2, varscan2
- AP2A1 | c.1391G>A p.R464H | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV62817319; called by muse, mutect2, varscan2
- AP2M1 | c.590C>T p.S197L | Missense Mutation (SNP) | VAF 26/72 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.432); catalogued as COSV99490827; called by muse, mutect2, varscan2
- ARF5 | c.295C>T p.R99W | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.999); catalogued as COSV50002181; called by muse, mutect2, varscan2
- ARFGEF2 | c.2297C>T p.A766V | Missense Mutation (SNP) | VAF 20/51 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64215572; called by muse, mutect2, varscan2
- ARIH1 | c.886C>T p.R296C | Missense Mutation (SNP) | VAF 45/123 reads (37%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.823); catalogued as rs1259128502, COSV65911454; called by muse, mutect2, varscan2
- ARL2BP | c.134T>C p.M45T | Missense Mutation (SNP) | VAF 70/164 reads (43%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.937); catalogued as rs398123053, CM137124, COSV54656919; called by muse, mutect2
- ARPP21 | c.1924C>A p.P642T | Missense Mutation (SNP) | VAF 45/113 reads (40%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as COSV99493585; called by muse, mutect2, varscan2
- ASAP1 | c.1009G>A p.G337R | Missense Mutation (SNP) | VAF 23/116 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100727956, COSV63048962; called by muse, mutect2, varscan2
- ATAD3A | c.1763C>T p.T588M | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT tolerated (0.21); PolyPhen benign (0.007); catalogued as rs769976477, COSV59231966, COSV59232952; called by muse, mutect2, varscan2
- ATP2C2 | c.2348C>A p.P783H | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52301928; called by muse, mutect2, varscan2
- ATP6V0A4 | c.1631C>T p.S544L | Missense Mutation (SNP) | VAF 11/54 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1276962394, CM162241, COSV59474065; called by muse, mutect2, varscan2
- ATP6V1G1 | c.265C>T p.R89W | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.443); catalogued as rs1025449499, COSV100928670; called by muse, mutect2, varscan2
- B4GALT2 | c.958A>G p.N320D | Missense Mutation (SNP) | VAF 15/34 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); catalogued as COSV58846428; called by muse, mutect2, varscan2
- BACE2 | c.928C>T p.R310C | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs967519091, COSV57744227; called by muse, mutect2, varscan2
- BANK1 | c.1301C>T p.A434V | Missense Mutation (SNP) | VAF 15/58 reads (26%) | SIFT tolerated (0.11); PolyPhen benign (0.011); catalogued as COSV59850805; called by muse, mutect2, varscan2
- BBS7 | c.1057C>T p.Q353* | Nonsense Mutation (SNP) | VAF 55/116 reads (47%) | catalogued as COSV52659881; called by muse, mutect2, varscan2
- BNIP1 | c.562C>T p.R188W | Missense Mutation (SNP) | VAF 35/81 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as rs372735517; called by muse, mutect2, varscan2
- BRD1 | c.2845G>A p.D949N (on ENST00000216267 / NM_001349940.1; = p.D1080N on NM_001304808.3) | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.998); catalogued as rs750190219, COSV53462101; called by muse, mutect2, varscan2
- BRD8 | c.3194del p.P1065Lfs*29 | Frame Shift Del (DEL) | VAF 9/79 reads (11%) | catalogued as COSV54725190; called by mutect2, pindel, varscan2
- BSN | c.6920G>A p.R2307Q | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT tolerated (0.59); PolyPhen benign (0.153); catalogued as rs781268137, COSV56528862; called by muse, mutect2, varscan2
- C12orf29 | c.656T>C p.I219T | Missense Mutation (SNP) | VAF 23/78 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.001); catalogued as rs767293985, COSV58356964; called by muse, mutect2, varscan2
- C16orf54 | c.163C>T p.R55C | Missense Mutation (SNP) | VAF 23/55 reads (42%) | SIFT tolerated, low confidence (0.07); PolyPhen probably damaging (0.951); catalogued as rs370898520, COSV100268589; called by muse, mutect2, varscan2
- C19orf57 | c.545C>T p.A182V | Missense Mutation (SNP) | VAF 12/13 reads (92%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.467); catalogued as rs765935675, COSV60968687; called by muse, mutect2, varscan2
- C1orf210 | c.200G>A p.R67H | Missense Mutation (SNP) | VAF 20/72 reads (28%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as rs897432979, COSV70682464; called by muse, mutect2, varscan2
- C20orf194 | c.313G>A p.V105I | Missense Mutation (SNP) | VAF 29/77 reads (38%) | SIFT tolerated (0.07); PolyPhen benign (0.028); catalogued as rs368687225; called by muse, mutect2, varscan2
- CABS1 | c.10G>A p.D4N | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.943); catalogued as rs1560515407, COSV56734713; called by muse, mutect2, varscan2
- CACNA1D | c.1805C>T p.T602M (on ENST00000350061 / NM_001128840.3; = p.T622M on NM_000720.4) | Missense Mutation (SNP) | VAF 82/217 reads (38%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.608); catalogued as rs765798948, COSV55466589; called by muse, mutect2, varscan2
- CACNA1H | c.5410G>A p.V1804M | Missense Mutation (SNP) | VAF 18/41 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs556889010, COSV52352447; called by muse, mutect2, varscan2
- CACNB2 | c.445C>T p.H149Y (on ENST00000324631 / NM_201596.3; = p.H94Y on NM_000724.4) | Missense Mutation (SNP) | VAF 20/52 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56649545; called by muse, mutect2, varscan2
- CACNG1 | c.625C>T p.R209W | Missense Mutation (SNP) | VAF 23/58 reads (40%) | SIFT tolerated (0.19); PolyPhen benign (0.425); catalogued as rs371885900; called by muse, mutect2, varscan2
- CALML3 | c.219G>T p.M73I | Missense Mutation (SNP) | VAF 23/56 reads (41%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.122); catalogued as COSV59450272; called by muse, mutect2, varscan2
- CAPN12 | c.355del p.R119Gfs*47 | Frame Shift Del (DEL) | VAF 56/158 reads (35%) | catalogued as rs1203549552, COSV61018747; called by mutect2, pindel, varscan2
- CBFA2T2 | c.425G>A p.R142Q | Missense Mutation (SNP) | VAF 19/37 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs549957667, COSV60076103; called by muse, mutect2, varscan2
- CCDC102A | c.1178G>A p.R393Q | Missense Mutation (SNP) | VAF 20/40 reads (50%) | SIFT tolerated (0.19); PolyPhen benign (0.028); catalogued as rs141307368, COSV50775835; called by muse, mutect2, varscan2
- CCDC34 | c.731del p.N244Mfs*28 | Frame Shift Del (DEL) | VAF 86/203 reads (42%) | catalogued as rs773019149; called by mutect2, varscan2
- CCDC78 | c.856C>T p.R286C | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as rs540243094, COSV53498703; ClinVar: uncertain significance; called by muse, mutect2
- CCDC89 | c.302T>C p.L101P | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV100320924; called by muse, mutect2
- CCK | c.314G>A p.R105H | Missense Mutation (SNP) | VAF 29/85 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs11559016, COSV58184472, COSV58184536; called by muse, mutect2, varscan2
- CCKAR | c.1132C>T p.R378C | Missense Mutation (SNP) | VAF 22/67 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55164304; called by muse, mutect2, varscan2
- CD1D | c.512G>A p.W171* | Nonsense Mutation (SNP) | VAF 35/92 reads (38%) | catalogued as COSV63810183; called by muse, mutect2, varscan2
- CD4 | c.498del p.K167Rfs*31 | Frame Shift Del (DEL) | VAF 17/48 reads (35%) | catalogued as rs781937995, COSV99163893; called by mutect2, varscan2
- CDADC1 | c.1126G>A p.A376T | Missense Mutation (SNP) | VAF 35/99 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV51913999; called by muse, mutect2, varscan2
- CDAN1 | c.1213C>A p.L405M | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99141216, COSV99142576; called by muse, mutect2
- CDK9 | c.850C>T p.R284C | Missense Mutation (SNP) | VAF 11/25 reads (44%) | SIFT tolerated (0.06); PolyPhen benign (0.019); catalogued as rs370938433; called by muse, mutect2, varscan2
- CDRT15 | c.457G>A p.A153T | Missense Mutation (SNP) | VAF 27/88 reads (31%) | SIFT tolerated, low confidence (0.22); PolyPhen possibly damaging (0.682); catalogued as COSV69755820; called by muse, mutect2, varscan2
- CEL | c.2173G>C p.A725P (on ENST00000673714; = p.A722P on NM_001807.6) | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.644); catalogued as rs202034862, COSV60826115, COSV60826621; called by mutect2, varscan2
- CELF2 | c.851C>T p.A284V (on ENST00000416382 / NM_001025077.3; = p.A291V on NM_006561.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.874); catalogued as rs1210960574, COSV59973362; called by muse, mutect2, varscan2
- CELSR2 | c.3298G>A p.V1100M | Missense Mutation (SNP) | VAF 6/9 reads (67%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.922); catalogued as rs751348890, COSV54770981; called by muse, mutect2, varscan2
- CEMP1 | c.4G>A p.G2S | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.97); catalogued as rs1390144276, COSV99566223; called by muse, mutect2, varscan2
- CERKL | c.1111C>T p.R371W (on ENST00000339098 / NM_001030311.2; = p.R345W on NM_201548.5) | Missense Mutation (SNP) | VAF 49/115 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs201231831, COSV59214370; called by muse, mutect2, varscan2
- CFAP100 | c.440A>G p.N147S | Missense Mutation (SNP) | VAF 21/41 reads (51%) | SIFT tolerated (0.51); PolyPhen benign (0.013); catalogued as COSV61504787; called by muse, mutect2, varscan2
- CFAP69 | c.1114A>G p.N372D | Missense Mutation (SNP) | VAF 35/94 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV60188783; called by muse, mutect2
- CHD4 | c.1373A>G p.Y458C (on ENST00000357008 / NM_001363606.2; = p.Y471C on NM_001273.5) | Missense Mutation (SNP) | VAF 22/69 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV58911781; called by muse, mutect2, varscan2
- CHRM4 | c.358G>A p.V120I | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.241); catalogued as rs1247534212, COSV63127569; called by muse, mutect2, varscan2
- CHRNB1 | c.1283C>T p.A428V | Missense Mutation (SNP) | VAF 22/41 reads (54%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as COSV60142548; called by muse, mutect2, varscan2
- CHST15 | c.1076C>T p.T359M | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT tolerated (0.13); PolyPhen benign (0.013); catalogued as rs767590394, COSV60566189; called by muse, mutect2, varscan2
- CHTF18 | c.1156G>A p.V386M | Missense Mutation (SNP) | VAF 17/37 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1299409975, COSV50102729; called by muse, mutect2, varscan2
- CLASP2 | c.1106G>A p.R369Q | Missense Mutation (SNP) | VAF 65/158 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as COSV100224493; called by muse, varscan2
- CLDN1 | c.194_195del p.K65Sfs*3 | Frame Shift Del (DEL) | VAF 25/55 reads (45%) | catalogued as rs1488536344; called by mutect2, pindel, varscan2
- CLSTN1 | c.111G>A p.W37* | Nonsense Mutation (SNP) | VAF 27/53 reads (51%) | catalogued as COSV63651523; called by muse, mutect2, varscan2
- CLUL1 | c.1022C>G p.T341R | Missense Mutation (SNP) | VAF 29/73 reads (40%) | SIFT tolerated (0.15); PolyPhen benign (0.012); catalogued as COSV58113700; called by muse, mutect2, varscan2
- CNOT11 | c.1348C>T p.R450C | Missense Mutation (SNP) | VAF 53/110 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56821246; called by muse, varscan2
- CNR2 | c.614T>C p.I205T | Missense Mutation (SNP) | VAF 19/52 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65694824; called by muse, mutect2, varscan2
- CNTNAP5 | c.2636C>T p.A879V | Missense Mutation (SNP) | VAF 28/89 reads (31%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.997); catalogued as COSV70514581; called by muse, mutect2, varscan2
- COBL | c.244A>T p.S82C | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54360098; called by muse, mutect2, varscan2
- COL11A1 | c.1635del p.P546Lfs*87 | Frame Shift Del (DEL) | VAF 120/333 reads (36%) | catalogued as COSV100615079, COSV62186140; called by mutect2, pindel, varscan2
- COL11A1 | c.1618C>T p.P540S | Missense Mutation (SNP) | VAF 51/131 reads (39%) | SIFT tolerated (0.27); PolyPhen benign (0.007); catalogued as COSV62199618; called by muse, mutect2, varscan2
- COL15A1 | c.723+1G>A p.X241_splice | Splice Site (SNP) | VAF 8/13 reads (62%) | catalogued as rs761706787, COSV100898046; called by muse, mutect2, varscan2
- COL22A1 | c.523G>A p.V175M | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1225221507, COSV57336822; called by muse, mutect2, varscan2
- COL6A3 | c.8008G>A p.A2670T | Missense Mutation (SNP) | VAF 11/59 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as rs398124135, COSV55112590; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COLGALT1 | c.1594C>T p.H532Y | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); catalogued as COSV99395322; called by muse, mutect2, varscan2
- CPOX | c.983G>A p.R328H | Missense Mutation (SNP) | VAF 29/75 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs749579807, COSV51640003; called by muse, mutect2, varscan2
- CPT1A | c.1126G>A p.G376R | Missense Mutation (SNP) | VAF 11/24 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.963); catalogued as rs755556780, COSV55760574, COSV55761767; called by muse, mutect2, varscan2
- CSAD | c.1294G>A p.E432K (on ENST00000444623 / NM_001244705.2; = p.E459K on NM_015989.5) | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT tolerated (0.49); PolyPhen benign (0.001); catalogued as COSV57245186; called by muse, mutect2, varscan2
- CSF1R | c.2467G>C p.A823P | Missense Mutation (SNP) | VAF 7/52 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99643314; called by muse, mutect2, varscan2
- CSK | c.1309C>T p.R437* | Nonsense Mutation (SNP) | VAF 4/33 reads (12%) | catalogued as COSV54975950; called by muse, mutect2, varscan2
- CSMD3 | c.10920del p.F3640Lfs*61 (on ENST00000297405 / NM_001363185.1; = p.F3471Lfs*61 on NM_052900.3) | Frame Shift Del (DEL) | VAF 11/33 reads (33%) | catalogued as rs766438669; called by mutect2, pindel, varscan2
- CST8 | c.275G>A p.R92H | Missense Mutation (SNP) | VAF 17/45 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.326); catalogued as rs149763863, COSV55672000; called by muse, mutect2, varscan2
- CTNNA2 | c.2018C>T p.A673V | Missense Mutation (SNP) | VAF 49/113 reads (43%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.837); catalogued as COSV58152383; called by muse, mutect2, varscan2
- CTNNA3 | c.2568dup p.P857Tfs*4 | Frame Shift Ins (INS) | VAF 56/130 reads (43%) | catalogued as rs759618368; called by mutect2, varscan2
- CUBN | c.4622G>A p.R1541Q | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV64708383, COSV64728482; called by muse, mutect2, varscan2
- CXCL5 | c.58G>A p.A20T | Missense Mutation (SNP) | VAF 31/89 reads (35%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as COSV56019285; called by muse, mutect2, varscan2
- DAPK1 | c.3775C>T p.R1259W | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as rs771500801, COSV63783862; called by muse, mutect2, varscan2
- DCAF1 | c.3755T>C p.I1252T | Missense Mutation (SNP) | VAF 32/77 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.892); catalogued as COSV60047030; called by muse, mutect2, varscan2
- DCAF1 | c.1114T>G p.F372V | Missense Mutation (SNP) | VAF 48/147 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV60047038; called by muse, mutect2, varscan2
- DCAF12L1 | c.238G>T p.V80L | Missense Mutation (SNP) | VAF 38/115 reads (33%) | SIFT tolerated (0.15); PolyPhen benign (0.097); catalogued as COSV64422857; called by muse, mutect2, varscan2
- DCAF17 | c.220T>C p.C74R | Missense Mutation (SNP) | VAF 80/163 reads (49%) | SIFT deleterious (0); PolyPhen benign (0.084); catalogued as COSV64546252; called by muse, mutect2, varscan2
- DDX43 | c.250G>A p.G84S | Missense Mutation (SNP) | VAF 23/42 reads (55%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.471); catalogued as COSV64836905; called by muse, mutect2, varscan2
- DENND4C | c.3836G>A p.R1279H (on ENST00000434457 / NM_001330640.2; = p.R1230H on NM_017925.7) | Missense Mutation (SNP) | VAF 36/140 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1046400679, COSV63008762; called by muse, mutect2, varscan2
- DEPTOR | c.974C>T p.P325L | Missense Mutation (SNP) | VAF 39/92 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.746); catalogued as rs147092773; called by muse, mutect2, varscan2
- DIP2C | c.3296C>T p.A1099V | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs1356539941, COSV55151694; called by muse, mutect2, varscan2
- DLGAP1 | c.1115G>A p.R372Q | Missense Mutation (SNP) | VAF 28/70 reads (40%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.975); catalogued as rs1188288808, COSV59839385; called by muse, mutect2, varscan2
- DMD | c.9825G>T p.E3275D | Missense Mutation (SNP) | VAF 30/88 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV58957206; called by muse, varscan2
- DMRT3 | c.1285G>A p.A429T | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0); catalogued as rs375503288; called by muse, mutect2, varscan2
- DMTF1 | c.508C>T p.R170C | Missense Mutation (SNP) | VAF 51/163 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.844); catalogued as rs559006713, COSV58685724; called by muse, mutect2, varscan2
- DNAH1 | c.7420C>T p.R2474C | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1228450839, COSV70237162; called by muse, mutect2, varscan2
- DNAH1 | c.11974A>G p.T3992A | Missense Mutation (SNP) | VAF 18/41 reads (44%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99964043; called by muse, mutect2, varscan2
- DNAH9 | c.7694G>A p.R2565Q | Missense Mutation (SNP) | VAF 29/68 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs147989905; called by muse, mutect2, varscan2
- DNM3 | c.523A>G p.T175A | Missense Mutation (SNP) | VAF 7/95 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.349); catalogued as rs1213566950, COSV100798733; called by muse, mutect2
- DNTT | c.733C>T p.R245* | Nonsense Mutation (SNP) | VAF 48/128 reads (38%) | catalogued as rs369785092; called by muse, mutect2, varscan2
- DOCK11 | c.5845G>T p.G1949C | Missense Mutation (SNP) | VAF 104/277 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52248458; called by muse, mutect2, varscan2
- DOCK8 | c.1177C>T p.R393C | Missense Mutation (SNP) | VAF 21/51 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs749367316, COSV66636293; called by muse, mutect2, varscan2
- DRGX | c.712G>A p.A238T | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0); catalogued as rs775648598, COSV65136016, COSV65137703; called by muse, mutect2, varscan2
- DSTN | c.308dup p.L103Ffs*12 | Frame Shift Ins (INS) | VAF 37/107 reads (35%) | catalogued as rs750962255; called by mutect2, varscan2
- DTNA | c.655C>A p.P219T | Missense Mutation (SNP) | VAF 39/81 reads (48%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV52028310; called by muse, mutect2, varscan2
- EBP | c.622del p.V208* | Frame Shift Del (DEL) | VAF 24/97 reads (25%) | catalogued as COSV52142341; called by mutect2, pindel, varscan2
- ECT2 | c.2630G>A p.R877H (on ENST00000392692 / NM_001349098.2; = p.R846H on NM_018098.6 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 27/77 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.015); catalogued as rs771541610, COSV51694973; called by muse, mutect2, varscan2
- EDIL3 | c.160T>G p.F54V | Missense Mutation (SNP) | VAF 40/219 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.902); catalogued as COSV56923498; called by muse, mutect2
- EEF1AKNMT | c.718G>A p.E240K (on ENST00000361735 / NM_015935.5; = p.E154K on NM_014955.3) | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT tolerated (0.27); PolyPhen benign (0.009); catalogued as rs760332211, COSV100676069; called by mutect2, varscan2
- EEF2K | c.1850C>T p.A617V | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs747482915, COSV53785509; called by mutect2, varscan2
- EFCAB6 | c.2161G>A p.V721M | Missense Mutation (SNP) | VAF 40/117 reads (34%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as rs148685975, COSV53071130; called by muse, mutect2, varscan2
- EHD2 | c.1495G>A p.G499S | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs781614465, COSV99621487, COSV99622288; called by mutect2, varscan2
- EIF4G1 | c.3796G>A p.V1266M (on ENST00000346169 / NM_198241.3; = p.V1071M on NM_004953.5) | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs896343202, COSV100072368; called by muse, mutect2, varscan2
- ELOA2 | c.967C>T p.R323W | Missense Mutation (SNP) | VAF 21/45 reads (47%) | SIFT tolerated (0.19); PolyPhen benign (0.183); catalogued as rs762067131, COSV55309631; called by muse, mutect2, varscan2
- ENTR1 | c.950A>G p.Y317C (on ENST00000357365 / NM_001039707.2; = p.Y294C on NM_006643.4) | Missense Mutation (SNP) | VAF 6/57 reads (11%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.849); catalogued as COSV53743529; called by muse, mutect2
- EPB41L1 | c.2480G>A p.R827Q | Missense Mutation (SNP) | VAF 10/21 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs764328855, COSV52433235; called by muse, mutect2, varscan2
- EPB41L3 | c.560A>C p.K187T | Missense Mutation (SNP) | VAF 13/26 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59457505; called by muse, mutect2, varscan2
- EPHA3 | c.364C>A p.L122M | Missense Mutation (SNP) | VAF 25/81 reads (31%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.996); catalogued as COSV60715972; called by muse, mutect2, varscan2
- EPS8L3 | c.847C>T p.Q283* | Nonsense Mutation (SNP) | VAF 48/126 reads (38%) | catalogued as COSV62610696; called by muse, mutect2, varscan2
- ERG | c.172G>A p.V58I | Missense Mutation (SNP) | VAF 47/92 reads (51%) | SIFT tolerated (0.24); PolyPhen benign (0.003); catalogued as rs200306085, COSV55732038; called by muse, mutect2, varscan2
- ERICH6 | c.126G>T p.E42D | Missense Mutation (SNP) | VAF 19/33 reads (58%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0.063); catalogued as rs1054395102, COSV55803615; called by muse, mutect2, varscan2
- ETV4 | c.399dup p.R134Qfs*49 | Frame Shift Ins (INS) | VAF 12/59 reads (20%) | catalogued as rs745944421; called by mutect2, varscan2
- EXOC3L4 | c.470C>T p.T157M | Missense Mutation (SNP) | VAF 11/24 reads (46%) | SIFT tolerated (0.1); PolyPhen benign (0.374); catalogued as COSV66296020; called by muse, mutect2, varscan2
- F8 | c.3249G>A p.M1083I | Missense Mutation (SNP) | VAF 29/301 reads (10%) | SIFT tolerated (0.21); PolyPhen benign (0.006); catalogued as COSV64271268; called by muse, mutect2, varscan2
- F9 | c.1070G>T p.G357V | Missense Mutation (SNP) | VAF 11/73 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CD005438, CM940641, CM940642, COSV54382618, COSV54382664; called by muse, mutect2, varscan2
- FADS2 | c.584A>T p.H195L | Missense Mutation (SNP) | VAF 34/96 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.938); catalogued as COSV53902861; called by muse, mutect2, varscan2
- FAM102A | c.1090G>A p.G364S (on ENST00000373095 / NM_001035254.3; = p.G222S on NM_203305.2) | Missense Mutation (SNP) | VAF 21/54 reads (39%) | SIFT tolerated (1); PolyPhen probably damaging (0.999); catalogued as rs1385089221, COSV55947769; called by muse, mutect2, varscan2
- FAM214B | c.725G>A p.R242Q | Missense Mutation (SNP) | VAF 22/61 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs747386620, COSV59717729; called by muse, mutect2, varscan2
- FAM83C | c.736C>T p.R246C | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs777921694, COSV65584721; called by muse, mutect2, varscan2
- FAM83H | c.3361C>T p.R1121C | Missense Mutation (SNP) | VAF 17/36 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.549); catalogued as rs782236631, COSV62029239; called by muse, mutect2, varscan2
- FANCM | c.1193G>A p.R398Q | Missense Mutation (SNP) | VAF 33/90 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.408); catalogued as rs530233908, COSV57507209, COSV99951343; called by muse, mutect2, varscan2
- FANCM | c.5102A>G p.Q1701R | Missense Mutation (SNP) | VAF 24/117 reads (21%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as rs758177952, COSV57507218; called by muse, mutect2
- FARP1 | c.2764G>A p.V922I | Missense Mutation (SNP) | VAF 9/18 reads (50%) | SIFT tolerated (0.13); PolyPhen benign (0.13); catalogued as rs749424604, COSV60349539; called by muse, mutect2, varscan2
- FASTKD3 | c.572A>T p.D191V | Missense Mutation (SNP) | VAF 25/88 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.856); catalogued as COSV52947150; called by muse, mutect2, varscan2
- FAT4 | c.6640G>A p.A2214T | Missense Mutation (SNP) | VAF 24/64 reads (38%) | SIFT tolerated (0.12); PolyPhen benign (0.012); catalogued as rs149686118; called by muse, mutect2, varscan2
- FBN1 | c.3920G>A p.C1307Y | Missense Mutation (SNP) | VAF 53/141 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as CM074858, COSV57332090; called by muse, mutect2, varscan2
- FBP2 | c.430T>C p.S144P | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT tolerated (0.41); PolyPhen benign (0.012); catalogued as COSV100942229; called by muse, mutect2, varscan2
- FBXL19 | c.1733G>A p.R578H | Missense Mutation (SNP) | VAF 11/24 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.924); catalogued as COSV57942662; called by muse, mutect2, varscan2
- FGD3 | c.772G>A p.V258I | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT tolerated (0.06); PolyPhen benign (0.163); catalogued as rs371917520; called by muse, mutect2, varscan2
- FGF3 | c.404G>A p.R135Q | Missense Mutation (SNP) | VAF 21/55 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.142); catalogued as rs199801193, COSV61925902; called by muse, mutect2, varscan2
- FGF5 | c.293G>A p.G98D | Missense Mutation (SNP) | VAF 22/67 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV56892149; called by muse, mutect2, varscan2
- FLG | c.11870A>G p.H3957R | Missense Mutation (SNP) | VAF 12/78 reads (15%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as COSV100912342; called by muse, mutect2
- FLG | c.2639C>A p.S880Y | Missense Mutation (SNP) | VAF 67/192 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as rs754201216, COSV64250863; called by muse, varscan2
- FLT4 | c.2287G>A p.V763M | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as COSV56110735; called by muse, mutect2, varscan2
- FLT4 | c.1430G>A p.R477Q | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT tolerated (0.07); PolyPhen benign (0.184); catalogued as rs755736057, COSV56100911; called by muse, mutect2
- FNDC1 | c.2426G>A p.R809Q | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.031); catalogued as COSV51931781; called by muse, mutect2, varscan2
- FOXI1 | c.776del p.G259Afs*27 | Frame Shift Del (DEL) | VAF 9/21 reads (43%) | catalogued as CM071772; called by mutect2, pindel, varscan2
- FOXS1 | c.241C>T p.R81C | Missense Mutation (SNP) | VAF 19/50 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs776132794, COSV54068006, COSV99640365; called by muse, mutect2, varscan2
- FPR1 | c.202G>A p.A68T | Missense Mutation (SNP) | VAF 44/115 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV59054029; called by muse, mutect2, varscan2
- FRG2 | c.308A>C p.K103T | Missense Mutation (SNP) | VAF 34/690 reads (5%) | SIFT tolerated (0.05); PolyPhen benign (0.104); catalogued as COSV101111592; called by muse, mutect2
- FZD3 | c.1754A>G p.Y585C | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT tolerated (0.18); PolyPhen benign (0.006); catalogued as COSV53538020; called by muse, mutect2, varscan2
- GABBR2 | c.1339G>A p.D447N | Missense Mutation (SNP) | VAF 33/88 reads (38%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.985); catalogued as rs546835197, COSV52302159; called by muse, mutect2, varscan2
- GDA | c.74C>A p.P25H | Missense Mutation (SNP) | VAF 17/39 reads (44%) | SIFT tolerated (0.22); PolyPhen benign (0.01); catalogued as COSV52998242; called by muse, mutect2, varscan2
- GEMIN5 | c.4094C>T p.A1365V | Missense Mutation (SNP) | VAF 32/75 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV53564027; called by muse, mutect2, varscan2
- GK5 | c.460C>T p.R154* | Nonsense Mutation (SNP) | VAF 60/150 reads (40%) | catalogued as rs775763865, COSV67485392; called by muse, mutect2, varscan2
- GLCE | c.224A>G p.E75G | Missense Mutation (SNP) | VAF 22/93 reads (24%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.227); catalogued as COSV99962686; called by muse, mutect2, varscan2
- GLUD2 | c.229G>A p.G77S | Missense Mutation (SNP) | VAF 38/92 reads (41%) | SIFT tolerated (0.17); PolyPhen benign (0.036); catalogued as COSV60153370; called by muse, mutect2, varscan2
- GNAT1 | c.515G>A p.R172H | Missense Mutation (SNP) | VAF 15/52 reads (29%) | SIFT tolerated (0.09); PolyPhen benign (0.039); catalogued as COSV50028704; called by muse, mutect2, varscan2
- GNL2 | c.326T>G p.V109G | Missense Mutation (SNP) | VAF 44/130 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV66079831, COSV66081855; called by muse, mutect2, varscan2
- GPR152 | c.476C>T p.A159V | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV56888379; called by muse, mutect2, varscan2
- GPR171 | c.850C>A p.L284M | Missense Mutation (SNP) | VAF 27/120 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV99854977; called by muse, mutect2, varscan2
- GPR35 | c.406G>A p.V136M | Missense Mutation (SNP) | VAF 10/17 reads (59%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.863); catalogued as rs143712491; called by muse, mutect2, varscan2
- GPR83 | c.757C>A p.L253I | Missense Mutation (SNP) | VAF 17/55 reads (31%) | SIFT deleterious (0.05); PolyPhen benign (0.125); catalogued as COSV54721024; called by muse, mutect2, varscan2
- GRINA | c.72del p.Q26Sfs*142 | Frame Shift Del (DEL) | VAF 14/30 reads (47%) | catalogued as rs781965675; called by mutect2, varscan2
- GRM5 | c.1575G>T p.K525N | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.812); catalogued as COSV59632326; called by muse, mutect2, varscan2
- GRM7 | c.1096G>A p.E366K | Missense Mutation (SNP) | VAF 30/99 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1559306156, COSV63159229, COSV63162440; called by muse, mutect2, varscan2
- GRM8 | c.1840G>A p.V614M | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs760774902, COSV58874182; called by muse, mutect2, varscan2
- GSE1 | c.1483_1485del p.E495del | In Frame Del (DEL) | VAF 18/42 reads (43%) | catalogued as rs758757723; called by pindel, varscan2
- GSN | c.878C>T p.A293V | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as rs1479845895, COSV58001875; called by muse, mutect2, varscan2
- GTF2F1 | c.1168C>T p.P390S | Missense Mutation (SNP) | VAF 12/18 reads (67%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV66727241; called by muse, mutect2, varscan2
- GYS1 | c.2083C>T p.R695C | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.446); catalogued as rs1317731883, COSV54405645; called by muse, mutect2, varscan2
- GZMB | c.436G>A p.G146S | Missense Mutation (SNP) | VAF 18/45 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs757031846, COSV53540212; called by muse, mutect2, varscan2
- HCN1 | c.769G>C p.V257L | Missense Mutation (SNP) | VAF 33/77 reads (43%) | SIFT tolerated (0.25); PolyPhen benign (0.02); catalogued as COSV57533736, COSV57539644; called by muse, mutect2, varscan2
- HECTD4 | c.7393G>A p.V2465M | Missense Mutation (SNP) | VAF 21/54 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.656); catalogued as rs372438469; called by muse, mutect2, varscan2
- HEPACAM | c.619G>A p.V207M | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs201870421, COSV53432764; called by muse, mutect2, varscan2
- HERC6 | c.1657G>A p.E553K | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT tolerated (0.65); PolyPhen benign (0.025); catalogued as rs768780766, COSV52035286, COSV99986374; called by muse, mutect2, varscan2
- HK1 | c.1174G>A p.A392T | Missense Mutation (SNP) | VAF 24/80 reads (30%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.946); catalogued as rs140290094; called by muse, mutect2, varscan2
- HLA-DPB1 | c.25G>C p.A9P | Missense Mutation (SNP) | VAF 19/38 reads (50%) | SIFT deleterious (0.01); PolyPhen benign (0.312); catalogued as COSV101331083; called by muse, mutect2, varscan2
- HMBS | c.95G>A p.R32H | Missense Mutation (SNP) | VAF 29/63 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs746673847, CM090525, COSV53830369; called by muse, mutect2, varscan2
- HNRNPUL1 | c.71G>A p.G24D | Missense Mutation (SNP) | VAF 9/14 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); catalogued as COSV54567313; called by muse, mutect2, varscan2
- HOMER1 | c.380C>A p.P127H | Missense Mutation (SNP) | VAF 44/90 reads (49%) | SIFT tolerated (0.59); PolyPhen benign (0.001); catalogued as COSV99981547; called by muse, mutect2, varscan2
- HOOK2 | c.2104C>T p.R702C | Missense Mutation (SNP) | VAF 33/59 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs371657591; called by muse, mutect2, varscan2
- HOXB2 | c.359C>T p.A120V | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT tolerated (0.37); PolyPhen benign (0.024); catalogued as rs1268803744, COSV57488412; called by muse, mutect2, varscan2
- HP | c.175C>T p.R59C | Missense Mutation (SNP) | VAF 25/172 reads (15%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.451); catalogued as rs373168016, COSV100577618; called by muse, mutect2, varscan2
- HSF5 | c.1726C>A p.H576N | Missense Mutation (SNP) | VAF 24/64 reads (38%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.419); catalogued as COSV60420023; called by muse, mutect2, varscan2
- HSPA12A | c.107T>C p.L36P | Missense Mutation (SNP) | VAF 9/19 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV100979994; called by muse, mutect2, varscan2
- ICAM4 | c.664C>T p.R222C | Missense Mutation (SNP) | VAF 23/25 reads (92%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.585); catalogued as rs151158164; called by muse, mutect2, varscan2
- ICMT | c.733C>T p.R245C | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as rs1163453055, COSV59474713; called by muse, mutect2, varscan2
- IFIT2 | c.815del p.K272Rfs*3 | Frame Shift Del (DEL) | VAF 15/63 reads (24%) | catalogued as COSV51078943; called by mutect2, pindel, varscan2
- IFT172 | c.3560C>T p.A1187V | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53140250; called by muse, mutect2, varscan2
- IGHV3-13 | c.105dup p.S36Vfs*15 | Frame Shift Ins (INS) | VAF 6/34 reads (18%) | catalogued as rs781931078; called by mutect2, pindel
- IGKV3D-11 | c.230G>A p.G77D | Missense Mutation (SNP) | VAF 29/147 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.142); catalogued as rs191678148; called by muse, mutect2, varscan2
- IGSF8 | c.1648G>A p.V550M | Missense Mutation (SNP) | VAF 23/56 reads (41%) | SIFT deleterious (0.05); PolyPhen benign (0.388); catalogued as COSV58759301; called by muse, mutect2, varscan2
- IL1B | c.22G>A p.A8T | Missense Mutation (SNP) | VAF 33/70 reads (47%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs762704392, COSV54523409; called by muse, mutect2, varscan2
- IL1R2 | c.478C>T p.R160C | Missense Mutation (SNP) | VAF 25/50 reads (50%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.724); catalogued as rs367683772; called by muse, mutect2, varscan2
- IL1RL1 | c.482C>T p.A161V | Missense Mutation (SNP) | VAF 53/158 reads (34%) | SIFT tolerated (0.35); PolyPhen benign (0.041); catalogued as rs772536038, COSV52112814; called by muse, mutect2, varscan2
- IL2RG | c.359del p.K120Rfs*27 | Frame Shift Del (DEL) | VAF 43/140 reads (31%) | catalogued as CD159812; called by mutect2, pindel, varscan2
- INO80 | c.458G>T p.S153I | Missense Mutation (SNP) | VAF 47/118 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.166); catalogued as COSV62743072; called by muse, mutect2, varscan2
- INPP5D | c.1246G>A p.A416T (on ENST00000445964 / NM_001017915.3; = p.A415T on NM_005541.5) | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT tolerated (0.19); PolyPhen benign (0.297); catalogued as COSV64038643; called by muse, mutect2, varscan2
- INTS2 | c.2108T>C p.L703S | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.844); catalogued as COSV99248957; called by muse, mutect2
- INTS5 | c.1790C>T p.A597V | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT tolerated (0.6); PolyPhen benign (0.045); catalogued as rs749822254, COSV57952527; called by muse, mutect2, varscan2
- IRAK3 | c.1262T>C p.L421S | Missense Mutation (SNP) | VAF 15/71 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV54166399; called by muse, mutect2
- IRGC | c.194C>T p.A65V | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.728); catalogued as rs1241505652, COSV54983350; called by muse, mutect2, varscan2
- IRGC | c.460G>A p.A154T | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT tolerated (0.38); PolyPhen benign (0.037); catalogued as rs749054115, COSV54983121; called by muse, mutect2, varscan2
- IRS2 | c.2392G>A p.V798I | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT tolerated (0.47); PolyPhen benign (0.001); catalogued as rs767024195, COSV65477066; called by mutect2, varscan2
- IRS4 | c.587G>A p.R196H | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT tolerated (0.07); PolyPhen benign (0.012); catalogued as COSV64534489; called by muse, mutect2, varscan2
- IRX1 | c.594G>T p.K198N | Missense Mutation (SNP) | VAF 21/66 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.816); catalogued as COSV100116851; called by muse, mutect2, varscan2
- ITGAM | c.2261C>T p.A754V (on ENST00000648685 / NM_001145808.2; = p.A753V on NM_000632.4) | Missense Mutation (SNP) | VAF 8/86 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as rs375408663; called by mutect2, varscan2
- ITPR1 | c.4756C>T p.R1586C (on ENST00000354582; = p.R1571C on NM_002222.7) | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.595); catalogued as rs373619512, COSV100231723; called by muse, mutect2, varscan2
- KANK4 | c.1783A>G p.K595E | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.611); catalogued as COSV100587750; called by muse, mutect2, varscan2
- KATNB1 | c.1475G>A p.R492H | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.707); catalogued as rs782300636, COSV65549627; called by muse, varscan2
- KATNBL1 | c.433del p.S145Lfs*19 | Frame Shift Del (DEL) | VAF 65/187 reads (35%) | catalogued as rs1206265094; called by mutect2, pindel, varscan2
- KATNIP | c.394C>T p.R132* | Nonsense Mutation (SNP) | VAF 4/12 reads (33%) | catalogued as rs1215744227, COSV99852156; called by mutect2, varscan2
- KCMF1 | c.358G>A p.D120N | Missense Mutation (SNP) | VAF 25/76 reads (33%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.753); catalogued as rs779570237, COSV69053820, COSV69054939; called by muse, mutect2, varscan2
- KCNA1 | c.166G>A p.A56T | Missense Mutation (SNP) | VAF 22/69 reads (32%) | SIFT tolerated (0.51); PolyPhen benign (0.113); catalogued as COSV66838901; called by muse, mutect2, varscan2
- KCNA3 | c.1136G>A p.R379H | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63901363; called by muse, mutect2, varscan2
- KCNB1 | c.161G>A p.R54H | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT tolerated (0.55); PolyPhen possibly damaging (0.459); catalogued as COSV65568965; called by muse, mutect2, varscan2
- KCND1 | c.511C>T p.R171W | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.858); catalogued as rs1557058589, COSV54416249; called by muse, mutect2, varscan2
- KCND2 | c.71C>T p.S24L | Missense Mutation (SNP) | VAF 14/33 reads (42%) | SIFT tolerated (0.18); PolyPhen benign (0.036); catalogued as COSV58575204; called by muse, mutect2, varscan2
- KCND2 | c.799G>A p.V267M | Missense Mutation (SNP) | VAF 29/76 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1328226950, COSV58582117; called by muse, mutect2, varscan2
- KCNQ1 | c.1642G>T p.G548C | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99328748; called by muse, mutect2, varscan2
- KCNV2 | c.665C>T p.A222V | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.77); catalogued as rs745988476, COSV66057646; called by muse, mutect2, varscan2
- KCTD21 | c.56C>T p.A19V | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT tolerated (0.08); PolyPhen benign (0.017); catalogued as rs967439472, COSV60741535; called by muse, mutect2, varscan2
- KCTD3 | c.478C>T p.R160W | Missense Mutation (SNP) | VAF 45/128 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.582); catalogued as rs752225604, COSV52071200; called by muse, mutect2, varscan2
- KCTD3 | c.2416del p.S806Vfs*16 | Frame Shift Del (DEL) | VAF 28/81 reads (35%) | catalogued as rs754600318; called by mutect2, pindel, varscan2
- KIAA1755 | c.3492del p.R1165Gfs*38 | Frame Shift Del (DEL) | VAF 11/36 reads (31%) | catalogued as rs772495335; called by mutect2, pindel, varscan2
- KIF17 | c.1369C>T p.R457W | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as rs746302711, COSV56116701; called by muse, mutect2, varscan2
- KIFC3 | c.575C>T p.A192V | Missense Mutation (SNP) | VAF 37/84 reads (44%) | SIFT tolerated (0.18); PolyPhen benign (0.174); catalogued as rs781966062, COSV65553392; called by muse, mutect2, varscan2
- KIFC3 | c.434G>A p.R145Q | Missense Mutation (SNP) | VAF 14/32 reads (44%) | SIFT tolerated (0.14); PolyPhen benign (0.009); catalogued as COSV65553399; called by muse, mutect2, varscan2
- KLC2 | c.1184G>A p.R395H | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.894); catalogued as rs755415117, COSV57584550; called by muse, mutect2, varscan2
- KLHL17 | c.1573G>A p.V525M | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as rs1191165125, COSV100647625, COSV58533364; called by muse, mutect2, varscan2
- KLHL3 | c.457C>A p.L153M | Missense Mutation (SNP) | VAF 12/111 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59058413; called by muse, mutect2
- KLRG1 | c.41C>T p.T14M | Missense Mutation (SNP) | VAF 14/27 reads (52%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.818); catalogued as rs755055403, COSV56944720; called by muse, mutect2, varscan2
- KMT2A | c.2584C>T p.R862* | Nonsense Mutation (SNP) | VAF 23/57 reads (40%) | catalogued as COSV63282793; called by muse, mutect2, varscan2
- KNL1 | c.1322C>T p.S441F (on ENST00000346991 / NM_170589.5; = p.S415F on NM_144508.5) | Missense Mutation (SNP) | VAF 16/89 reads (18%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.991); catalogued as COSV61151764, COSV61161448; called by muse, mutect2, varscan2
- KRT17 | c.1204+1G>A p.X402_splice | Splice Site (SNP) | VAF 28/54 reads (52%) | catalogued as rs753628412, COSV60860249; called by muse, varscan2
- KRTAP10-4 | c.854G>A p.C285Y | Missense Mutation (SNP) | VAF 39/104 reads (38%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.869); catalogued as COSV59981968; called by muse, mutect2, varscan2
- KRTAP24-1 | c.460C>A p.Q154K | Missense Mutation (SNP) | VAF 38/109 reads (35%) | SIFT tolerated (0.17); PolyPhen benign (0.043); catalogued as COSV61090192; called by muse, mutect2, varscan2
- KRTAP8-1 | c.62A>G p.Y21C | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV61597932, COSV61598422; called by muse, mutect2, varscan2
- KTI12 | c.938T>C p.L313S | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.511); catalogued as COSV65406145; called by muse, mutect2
- L1CAM | c.202C>T p.R68C | Missense Mutation (SNP) | VAF 19/56 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1172761444, COSV62829158; called by muse, mutect2, varscan2
- L3MBTL2 | c.1447G>A p.A483T | Missense Mutation (SNP) | VAF 15/25 reads (60%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.455); catalogued as rs1370275224, COSV53436022; called by muse, mutect2, varscan2
- LAP3 | c.79C>T p.L27F | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT tolerated (0.74); PolyPhen benign (0); catalogued as COSV56902016; called by muse, mutect2, varscan2
- LFNG | c.545C>T p.A182V (on ENST00000222725 / NM_001040167.2; = p.A53V on NM_002304.2) | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as rs868274958, COSV56071452; called by muse, mutect2, varscan2
- LGALS4 | c.451G>A p.G151R | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs760505571, COSV57044049; called by muse, mutect2, varscan2
- LMF2 | c.1733G>A p.R578H | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs749758476, COSV53319407; called by muse, mutect2, varscan2
- LNPEP | c.1544G>A p.R515Q | Missense Mutation (SNP) | VAF 36/80 reads (45%) | SIFT tolerated (0.23); PolyPhen benign (0.34); catalogued as rs750360079, COSV51476278, COSV51482229; called by muse, mutect2, varscan2
- LNX1 | c.2116G>T p.A706S (on ENST00000263925 / NM_001126328.3; = p.A610S on NM_032622.2) | Missense Mutation (SNP) | VAF 13/192 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.527); catalogued as COSV55792807; called by muse, mutect2
- LRRC8A | c.1070G>A p.R357H | Missense Mutation (SNP) | VAF 21/42 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52189666; called by muse, mutect2, varscan2
- LRRK2 | c.1073C>T p.T358M | Missense Mutation (SNP) | VAF 31/92 reads (34%) | SIFT tolerated (0.09); PolyPhen benign (0.009); catalogued as rs141262110; ClinVar: conflicting interpretations of pathogenicity; called by muse, mutect2, varscan2
- LSAMP | c.856G>A p.G286S | Missense Mutation (SNP) | VAF 25/58 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1241093229, COSV61313156; called by muse, mutect2, varscan2
- LTB | c.503del p.G168Afs*18 | Frame Shift Del (DEL) | VAF 8/26 reads (31%) | catalogued as rs774553384; called by mutect2, pindel
- LUZP4 | c.43C>T p.P15S | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT tolerated (0.5); PolyPhen benign (0.026); catalogued as rs782689315, COSV64219821; called by muse, mutect2, varscan2
- LY75 | c.3364_3365del p.L1122Dfs*6 | Frame Shift Del (DEL) | VAF 28/100 reads (28%) | catalogued as rs760829285; called by pindel, varscan2
- MAGEH1 | c.122C>T p.A41V | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.001); catalogued as COSV61679285; called by muse, mutect2, varscan2
- MAGI1 | c.2096A>G p.H699R | Missense Mutation (SNP) | VAF 38/126 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58347009; called by muse, mutect2
- MAP1S | c.1345C>T p.Q449* | Nonsense Mutation (SNP) | VAF 9/17 reads (53%) | catalogued as COSV60724825; called by muse, varscan2
- MAP2K7 | c.727G>A p.D243N | Missense Mutation (SNP) | VAF 35/44 reads (80%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1156815343, COSV67607577, COSV67607584; called by muse, mutect2, varscan2
- MAP3K14 | c.86C>T p.T29M | Missense Mutation (SNP) | VAF 39/93 reads (42%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.143); catalogued as rs55820104, COSV100766583, COSV60924555; called by muse, mutect2, varscan2
- MAP3K9 | c.3046C>T p.R1016C (on ENST00000554752 / NM_001284230.1; = p.R1030C on NM_033141.4) | Missense Mutation (SNP) | VAF 17/27 reads (63%) | SIFT tolerated (0.08); PolyPhen benign (0.353); catalogued as rs201827381; called by muse, mutect2, varscan2
- MAP7D1 | c.68del p.P23Qfs*33 | Frame Shift Del (DEL) | VAF 16/49 reads (33%) | catalogued as rs761388884; called by mutect2, pindel, varscan2
- MARCKS | c.980del p.P327Qfs*42 | Frame Shift Del (DEL) | VAF 14/32 reads (44%) | catalogued as rs770972906; called by mutect2, pindel, varscan2
- MARCKSL1 | c.191C>T p.A64V | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.037); catalogued as rs1437768011, COSV61482472; called by muse, mutect2, varscan2
- MARK1 | c.426T>C p.G142= | Splice Region (SNP) | VAF 54/125 reads (43%) | catalogued as COSV65066789, COSV65071860; called by muse, mutect2
- MARVELD2 | c.383C>T p.S128L | Missense Mutation (SNP) | VAF 20/42 reads (48%) | SIFT tolerated (0.22); PolyPhen benign (0.278); catalogued as rs752573907, COSV57782581; called by muse, mutect2, varscan2
- MC3R | c.348G>T p.M116I | Missense Mutation (SNP) | VAF 6/60 reads (10%) | SIFT tolerated (0.36); PolyPhen benign (0.388); catalogued as COSV54765114; called by muse, mutect2
- MCF2L | c.696G>A p.T232= (on ENST00000375608; = p.T200= on NM_024979.4 and 1 other RefSeq transcript) | Splice Region (SNP) | VAF 4/10 reads (40%) | catalogued as rs770362075, COSV100983104; called by muse, mutect2, varscan2
- MCF2L2 | c.287C>T p.A96V | Missense Mutation (SNP) | VAF 11/63 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.961); catalogued as COSV61062282; called by muse, mutect2, varscan2
- MED1 | c.2030G>A p.R677H | Missense Mutation (SNP) | VAF 29/94 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.926); catalogued as rs746684915, COSV56128108; called by muse, mutect2, varscan2
- MEOX1 | c.614C>T p.A205V | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs747977868, COSV59356494; called by muse, mutect2, varscan2
- MGAT5 | c.1619A>G p.N540S | Missense Mutation (SNP) | VAF 40/113 reads (35%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as rs1460187058, COSV56101628; called by muse, mutect2, varscan2
- MIA3 | c.503dup p.N168Kfs*3 | Frame Shift Ins (INS) | VAF 24/92 reads (26%) | catalogued as rs756037599; called by mutect2, varscan2
- MICAL3 | c.4417C>T p.R1473W | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.333); catalogued as rs375690426; called by muse, mutect2, varscan2
- MIDEAS | c.939del p.N314Tfs*4 | Frame Shift Del (DEL) | VAF 16/32 reads (50%) | catalogued as rs762448666; called by pindel, varscan2
- MIDN | c.802G>A p.V268I | Missense Mutation (SNP) | VAF 30/44 reads (68%) | SIFT tolerated (0.43); PolyPhen benign (0.099); catalogued as rs138120774; called by muse, mutect2, varscan2
- MINK1 | c.2840G>T p.G947V | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as COSV53420388; called by muse, mutect2, varscan2
- MISP | c.1037G>A p.R346H | Missense Mutation (SNP) | VAF 9/12 reads (75%) | SIFT deleterious (0.02); PolyPhen benign (0.031); catalogued as rs771407225, COSV53118816; called by muse, mutect2, varscan2
- MKS1 | c.1528C>T p.R510W | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.394); catalogued as rs757310695, COSV56598488; called by muse, mutect2, varscan2
- MMP15 | c.964C>T p.R322W | Missense Mutation (SNP) | VAF 25/44 reads (57%) | SIFT deleterious (0); PolyPhen benign (0.23); catalogued as rs572888530, COSV54681797; called by muse, mutect2, varscan2
- MN1 | c.129del p.P45Lfs*8 | Frame Shift Del (DEL) | VAF 20/48 reads (42%) | catalogued as COSV56556167; called by mutect2, pindel, varscan2
- MPHOSPH6 | c.125A>T p.E42V | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs1416177833, COSV50737529; called by muse, mutect2, varscan2
- MRE11 | c.963dup p.N322* | Frame Shift Ins (INS) | VAF 19/164 reads (12%) | catalogued as rs1173177963; called by mutect2, pindel, varscan2
- MROH9 | c.615C>T p.N205= | Splice Region (SNP) | VAF 24/58 reads (41%) | catalogued as rs199761702; called by muse, mutect2, varscan2
- MRPL38 | c.344C>T p.A115V | Missense Mutation (SNP) | VAF 7/84 reads (8%) | SIFT tolerated (0.15); PolyPhen benign (0.014); catalogued as COSV58615182; called by muse, mutect2
- MTBP | c.1538A>T p.Y513F | Missense Mutation (SNP) | VAF 95/221 reads (43%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as COSV59966821; called by muse, mutect2, varscan2
- MTOR | c.4291G>A p.G1431R | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV63872788; called by muse, mutect2, varscan2
- MTREX | c.1648C>T p.Q550* | Nonsense Mutation (SNP) | VAF 4/46 reads (9%) | catalogued as COSV100044613; called by muse, mutect2
- MTSS1 | c.459del p.R155Efs*34 | Frame Shift Del (DEL) | VAF 25/87 reads (29%) | catalogued as rs1563799887; called by mutect2, varscan2
- MUC16 | c.4327C>A p.L1443M | Missense Mutation (SNP) | VAF 29/122 reads (24%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.003); catalogued as COSV67497557; called by muse, mutect2, varscan2
- MYCBP2 | c.3226A>T p.T1076S (on ENST00000357337; = p.T1114S on NM_015057.5) | Missense Mutation (SNP) | VAF 40/135 reads (30%) | SIFT tolerated (1); PolyPhen benign (0.055); catalogued as COSV62041362; called by muse, mutect2, varscan2
- MYH6 | c.2113C>T p.R705C | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs767124357, COSV62454978; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MYH7B | c.2306G>A p.R769Q | Missense Mutation (SNP) | VAF 9/19 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs769933919, COSV53416479; called by muse, mutect2, varscan2
- NAA35 | c.434C>T p.A145V | Missense Mutation (SNP) | VAF 32/75 reads (43%) | SIFT tolerated (1); PolyPhen benign (0.023); catalogued as COSV64486758; called by muse, mutect2, varscan2
- NACC2 | c.1165C>A p.L389M | Missense Mutation (SNP) | VAF 21/66 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53203369; called by muse, mutect2, varscan2
- NAGK | c.845G>A p.G282D | Missense Mutation (SNP) | VAF 31/134 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV54904265, COSV54904661; called by muse, mutect2, varscan2
- NARS1 | c.263G>T p.S88I | Missense Mutation (SNP) | VAF 13/158 reads (8%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as COSV99900758; called by muse, mutect2
- NDE1 | c.386G>A p.R129H | Missense Mutation (SNP) | VAF 22/55 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs761910819, COSV61270235; called by muse, mutect2, varscan2
- NDUFS1 | c.1346C>T p.P449L | Missense Mutation (SNP) | VAF 16/57 reads (28%) | SIFT tolerated (0.2); PolyPhen benign (0.02); catalogued as rs781249832, COSV51914164; called by muse, mutect2, varscan2
- NEB | c.4939G>A p.A1647T | Missense Mutation (SNP) | VAF 41/151 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as rs566604130, COSV50898584; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NECAB3 | c.583C>T p.R195C | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1234521299, COSV55778868; called by muse, mutect2, varscan2
- NEK8 | c.445G>A p.G149S | Missense Mutation (SNP) | VAF 14/32 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV52044209; called by muse, mutect2, varscan2
- NES | c.1176del p.T393Hfs*9 | Frame Shift Del (DEL) | VAF 19/43 reads (44%) | catalogued as rs759081520; called by mutect2, pindel, varscan2
- NEU1 | c.257C>T p.P86L | Missense Mutation (SNP) | VAF 20/44 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.346); catalogued as rs1196998777, COSV57669354; called by muse, mutect2, varscan2
- NEURL1 | c.292C>T p.R98C | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs61871259, COSV63915424; called by muse, mutect2, varscan2
- NINL | c.1943C>T p.A648V | Missense Mutation (SNP) | VAF 22/65 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.045); catalogued as rs141944908; called by muse, mutect2, varscan2
- NKAP | c.112C>T p.R38W | Missense Mutation (SNP) | VAF 35/72 reads (49%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.973); catalogued as rs1486378790, COSV65055893; called by muse, mutect2, varscan2
- NLK | c.576del p.F192Lfs*30 | Frame Shift Del (DEL) | VAF 34/129 reads (26%) | catalogued as COSV69407880; called by pindel, varscan2
- NMT1 | c.833A>G p.Q278R | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99365084; called by muse, mutect2
- NOD2 | c.1583del p.P528Qfs*235 | Frame Shift Del (DEL) | VAF 17/43 reads (40%) | catalogued as rs754073471; ClinVar: uncertain significance; called by mutect2, pindel, varscan2
- NR1H3 | c.601dup p.Q201Pfs*25 | Frame Shift Ins (INS) | VAF 20/38 reads (53%) | catalogued as rs779801455; called by mutect2, varscan2
- NR1H3 | c.881C>T p.A294V | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.039); catalogued as rs556085486, COSV68008777; called by muse, mutect2, varscan2
- NRCAM | c.1328C>T p.A443V (on ENST00000379028 / NM_001371124.1; = p.A437V on NM_005010.4 and 21 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 34/67 reads (51%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.913); catalogued as COSV61050575; called by muse, mutect2, varscan2
- NSA2 | c.364C>T p.P122S | Missense Mutation (SNP) | VAF 86/206 reads (42%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.703); catalogued as COSV57189122; called by muse, mutect2, varscan2
- NSRP1 | c.209C>A p.A70D | Missense Mutation (SNP) | VAF 90/212 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.226); catalogued as COSV55935796; called by muse, mutect2, varscan2
- NT5DC2 | c.1009-1G>T p.X337_splice | Splice Site (SNP) | VAF 22/56 reads (39%) | catalogued as COSV58743787; called by muse, mutect2, varscan2
- NTNG1 | c.61C>G p.Q21E | Missense Mutation (SNP) | VAF 19/53 reads (36%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.965); catalogued as COSV53990494; called by muse, mutect2, varscan2
- NTSR2 | c.995T>C p.L332P | Missense Mutation (SNP) | VAF 21/42 reads (50%) | SIFT deleterious (0.01); PolyPhen benign (0.4); catalogued as rs200323530, COSV60992938; called by muse, mutect2
- NUDT11 | c.156G>T p.M52I | Missense Mutation (SNP) | VAF 25/103 reads (24%) | SIFT tolerated (0.32); PolyPhen benign (0.014); catalogued as COSV65665510; called by muse, mutect2, varscan2
- NUMB | c.706G>A p.A236T (on ENST00000355058; = p.A225T on NM_003744.5) | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as COSV61832481; called by muse, mutect2, varscan2
- NUP214 | c.681del p.V228Sfs*29 | Frame Shift Del (DEL) | VAF 12/78 reads (15%) | catalogued as rs771913112, COSV63912486; called by mutect2, varscan2
- NXPH1 | c.712A>T p.I238F | Missense Mutation (SNP) | VAF 23/77 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1479674234, COSV68320080; called by muse, mutect2, varscan2
- OBI1 | c.1946_1947del p.E649Vfs*15 | Frame Shift Del (DEL) | VAF 24/70 reads (34%) | catalogued as rs761617267; called by pindel, varscan2
- OGDH | c.142C>T p.P48S | Missense Mutation (SNP) | VAF 16/76 reads (21%) | SIFT tolerated (0.69); PolyPhen benign (0.013); catalogued as rs1244940674, COSV99759742; called by muse, mutect2, varscan2
- OPRD1 | c.913G>A p.A305T | Missense Mutation (SNP) | VAF 20/42 reads (48%) | SIFT deleterious (0.03); PolyPhen benign (0.313); catalogued as COSV52384016; called by muse, mutect2, varscan2
- OPTN | c.76del p.H26Tfs*19 | Frame Shift Del (DEL) | VAF 7/27 reads (26%) | catalogued as rs753966040; called by mutect2, pindel, varscan2
- OR10J3 | c.160C>A p.H54N | Missense Mutation (SNP) | VAF 35/94 reads (37%) | SIFT deleterious (0.03); PolyPhen benign (0.184); catalogued as COSV59955751; called by muse, mutect2, varscan2
- OR11L1 | c.365G>A p.R122H | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs536790643, COSV63313548; called by muse, mutect2
- OR13G1 | c.614T>C p.I205T | Missense Mutation (SNP) | VAF 25/67 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.038); catalogued as COSV100687616; called by muse, mutect2, varscan2
- OR1B1 | c.941del p.V314Gfs*3 | Frame Shift Del (DEL) | VAF 28/83 reads (34%) | catalogued as COSV59172505; called by mutect2, pindel, varscan2
- OR1C1 | c.934C>T p.Q312* | Nonsense Mutation (SNP) | VAF 7/22 reads (32%) | catalogued as COSV68715557; called by muse, mutect2, varscan2
- OR2T10 | c.914T>C p.L305P | Missense Mutation (SNP) | VAF 27/63 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.91); catalogued as COSV57898599; called by muse, mutect2, varscan2
- OR2W3 | c.400G>A p.V134M | Missense Mutation (SNP) | VAF 58/167 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); catalogued as rs769134275, COSV64458195; called by muse, mutect2, varscan2
- OR2Z1 | c.643G>A p.A215T | Missense Mutation (SNP) | VAF 40/66 reads (61%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as rs1398743549, COSV60693438; called by muse, mutect2, varscan2
- OR4C16 | c.512T>C p.V171A | Missense Mutation (SNP) | VAF 40/96 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.685); catalogued as COSV58944530; called by muse, mutect2
- OR4N2 | c.494G>A p.R165H | Missense Mutation (SNP) | VAF 60/130 reads (46%) | SIFT tolerated (0.71); PolyPhen benign (0.009); catalogued as rs1185775789, COSV60050197, COSV60054028; called by muse, mutect2, varscan2
- OR51B4 | c.496T>C p.C166R | Missense Mutation (SNP) | VAF 40/133 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66517928; called by muse, mutect2
- OR5H1 | c.158C>A p.P53H | Missense Mutation (SNP) | VAF 177/472 reads (38%) | SIFT tolerated (0.17); PolyPhen benign (0.049); catalogued as COSV100641622, COSV100641641; called by muse, mutect2, varscan2
- OTUD5 | c.478G>A p.A160T | Missense Mutation (SNP) | VAF 11/26 reads (42%) | SIFT tolerated (0.17); PolyPhen benign (0.012); catalogued as COSV50240356; called by muse, mutect2, varscan2
- PALM | c.65G>A p.R22Q | Missense Mutation (SNP) | VAF 16/20 reads (80%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.836); catalogued as rs1187942899, COSV52771266; called by muse, mutect2, varscan2
- PANX2 | c.821C>T p.A274V | Missense Mutation (SNP) | VAF 7/12 reads (58%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as rs1393190491, COSV50302887; called by muse, mutect2, varscan2
- PAPLN | c.2783G>A p.R928Q (on ENST00000554301; = p.R901Q on NM_173462.4) | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT tolerated (1); PolyPhen benign (0.02); catalogued as rs753673675, COSV53724839; called by muse, mutect2, varscan2
- PAPPA | c.4776+2T>C p.X1592_splice | Splice Site (SNP) | VAF 6/22 reads (27%) | catalogued as COSV100075545, COSV60287559; called by muse, mutect2, varscan2
- PARD6G | c.464C>T p.T155M | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as COSV62063043; called by muse, mutect2, varscan2
- PARN | c.917C>T p.A306V | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as rs201362263; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PCDHA1 | c.1609G>A p.A537T | Missense Mutation (SNP) | VAF 12/76 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.993); catalogued as COSV65377231; called by muse, mutect2, varscan2
- PCDHA11 | c.680G>A p.R227Q | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs990827650, COSV56477132; called by muse, mutect2, varscan2
- PCDHA7 | c.451C>T p.R151W | Missense Mutation (SNP) | VAF 70/180 reads (39%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.503); catalogued as COSV65348003; called by muse, mutect2, varscan2
- PCDHA8 | c.86G>A p.G29D | Missense Mutation (SNP) | VAF 20/50 reads (40%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.905); catalogued as rs782072047, COSV65336449, COSV65339402; called by muse, varscan2
- PCDHA8 | c.1073C>A p.P358H | Missense Mutation (SNP) | VAF 22/176 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV100971087, COSV65337029; called by muse, mutect2, varscan2
- PCDHB14 | c.1381C>T p.R461C | Missense Mutation (SNP) | VAF 25/54 reads (46%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.082); catalogued as rs868908812, COSV53391631, COSV99505561; called by muse, mutect2, varscan2
- PCDHGA1 | c.1933G>A p.A645T | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.158); catalogued as COSV65300142; called by muse, mutect2, varscan2
- PCDHGA1 | c.1990G>A p.V664M | Missense Mutation (SNP) | VAF 36/91 reads (40%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.627); catalogued as rs768240411, COSV65296000; called by muse, mutect2, varscan2
- PCDHGA4 | c.401T>C p.V134A | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.009); catalogued as COSV99548332; called by muse, mutect2
- PCDHGA8 | c.1619C>T p.P540L | Missense Mutation (SNP) | VAF 24/63 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.841); catalogued as rs1561648568, COSV54043777; called by muse, mutect2, varscan2
- PCF11 | c.884G>A p.R295Q | Missense Mutation (SNP) | VAF 15/37 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1322320178, COSV100018150, COSV53538266; called by muse, mutect2, varscan2
- PCOLCE2 | c.1000G>A p.A334T | Missense Mutation (SNP) | VAF 49/121 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.953); catalogued as rs770152757, COSV56002431; called by muse, mutect2, varscan2
- PDCD11 | c.460A>C p.S154R | Missense Mutation (SNP) | VAF 30/115 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as COSV63935561; called by muse, mutect2, varscan2
- PDCL3 | c.43C>T p.R15C | Missense Mutation (SNP) | VAF 22/110 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.718); catalogued as rs777385726, COSV51809791; called by muse, mutect2, varscan2
- PDCL3 | c.340T>A p.W114R | Missense Mutation (SNP) | VAF 27/82 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV51810444; called by muse, mutect2, varscan2
- PDHA2 | c.674A>T p.Y225F | Missense Mutation (SNP) | VAF 17/36 reads (47%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.942); catalogued as COSV54782320, COSV99756887; called by muse, mutect2, varscan2
- PDHA2 | c.853T>C p.Y285H | Missense Mutation (SNP) | VAF 15/35 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54782335; called by muse, mutect2, varscan2
- PELP1 | c.935G>A p.R312Q | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as rs373744745, COSV52585887; called by muse, mutect2, varscan2
- PGM1 | c.125G>C p.S42T | Missense Mutation (SNP) | VAF 15/32 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.689); catalogued as rs374207269, COSV64304666; called by muse, mutect2, varscan2
- PHLDB2 | c.1882C>T p.L628F | Missense Mutation (SNP) | VAF 19/103 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV67316506; called by muse, mutect2, varscan2
- PIM3 | c.671G>A p.R224H | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.891); catalogued as COSV100638449; called by muse, mutect2, varscan2
- PKD1 | c.3490G>A p.G1164R | Missense Mutation (SNP) | VAF 24/49 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99239212; called by muse, mutect2, varscan2
- PKP2 | c.1298T>C p.V433A | Missense Mutation (SNP) | VAF 12/90 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.709); catalogued as rs953284543, COSV99298577; called by muse, mutect2
- PLA2G15 | c.695dup p.V233Rfs*47 | Frame Shift Ins (INS) | VAF 6/13 reads (46%) | catalogued as rs763871300; called by mutect2, varscan2
- PLA2G4D | c.664C>T p.R222C | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as rs781439174, COSV51824264; called by muse, mutect2, varscan2
- PLA2G4F | c.2497G>A p.A833T | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT tolerated (0.16); PolyPhen benign (0.397); catalogued as rs775787567, COSV51829753; called by muse, mutect2, varscan2
- PLCB2 | c.1826G>A p.R609H | Missense Mutation (SNP) | VAF 54/144 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs376425228; called by muse, mutect2, varscan2
- PLEKHG4B | c.3805C>T p.R1269C (on ENST00000283426; = p.R1625C on NM_052909.5) | Missense Mutation (SNP) | VAF 7/14 reads (50%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.042); catalogued as rs115163479, COSV52055777; called by muse, mutect2, varscan2
- PLG | c.359del p.N120Mfs*110 | Frame Shift Del (DEL) | VAF 39/142 reads (27%) | catalogued as COSV51983750; called by mutect2, pindel, varscan2
- PLXNA1 | c.2560G>A p.A854T | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT tolerated (0.59); PolyPhen possibly damaging (0.487); catalogued as rs371145234; called by muse, mutect2, varscan2
- PLXNA3 | c.40G>A p.V14M | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT tolerated (0.34); PolyPhen benign (0.005); catalogued as rs782271984, COSV63755940; called by mutect2, varscan2
- PLXNA3 | c.49del p.A17Pfs*12 | Frame Shift Del (DEL) | VAF 12/46 reads (26%) | catalogued as rs782247826; called by mutect2, varscan2
- PLXNB1 | c.4880G>A p.R1627H | Missense Mutation (SNP) | VAF 17/41 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs746314397, COSV56492454; called by muse, mutect2, varscan2
- PNPLA6 | c.3511G>A p.G1171R (on ENST00000414982 / NM_001166111.2; = p.G1123R on NM_006702.5) | Missense Mutation (SNP) | VAF 12/17 reads (71%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs776490050, COSV55386098, COSV99653965; called by muse, mutect2, varscan2
- PPP2R3B | c.887C>T p.A296V | Missense Mutation (SNP) | VAF 10/121 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.383); catalogued as rs760244257, COSV66813342; called by muse, mutect2
- PPP2R5C | c.1051A>G p.N351D | Missense Mutation (SNP) | VAF 16/82 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.494); catalogued as COSV58277000; called by muse, mutect2, varscan2
- PPRC1 | c.2819dup p.P941Tfs*75 | Frame Shift Ins (INS) | VAF 32/90 reads (36%) | catalogued as rs768056539; called by mutect2, varscan2
- PRAM1 | c.1090G>A p.A364T | Missense Mutation (SNP) | VAF 72/86 reads (84%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.511); catalogued as rs1372347069, COSV55317442; called by muse, mutect2, varscan2
- PRCC | c.275del p.P92Hfs*5 | Frame Shift Del (DEL) | VAF 14/60 reads (23%) | catalogued as COSV54858092; called by mutect2, pindel, varscan2
- PRKAR2A | c.214G>A p.A72T | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT tolerated (0.53); PolyPhen benign (0.001); catalogued as COSV55554626; called by muse, mutect2, varscan2
- PRL | c.163C>T p.H55Y | Missense Mutation (SNP) | VAF 42/112 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.304); catalogued as COSV60593822; called by muse, mutect2, varscan2
- PRLHR | c.208G>A p.V70M | Missense Mutation (SNP) | VAF 32/71 reads (45%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.948); catalogued as COSV53305359; called by muse, mutect2, varscan2
- PRMT5 | c.1600C>T p.R534C | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1307386753, COSV53548584; called by muse, mutect2, varscan2
- PRSS8 | c.802C>T p.P268S | Missense Mutation (SNP) | VAF 12/69 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54899450; called by muse, mutect2, varscan2
- PSD | c.1000C>T p.R334W | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.249); catalogued as rs754826345, COSV50044216, COSV50064658; called by muse, mutect2, varscan2
- PTEN | c.313del p.C105Vfs*8 | Frame Shift Del (DEL) | VAF 43/123 reads (35%) | catalogued as COSV64296825; called by mutect2, pindel, varscan2
- PTH1R | c.837G>A p.A279= | Splice Region (SNP) | VAF 29/58 reads (50%) | catalogued as rs1307308968, COSV57315631; called by muse, mutect2, varscan2
- PTPN21 | c.1606G>A p.A536T | Missense Mutation (SNP) | VAF 3/12 reads (25%) | SIFT tolerated (0.8); PolyPhen probably damaging (0.995); catalogued as rs1438347737, COSV60851088; called by muse, mutect2
- PTPN5 | c.864A>C p.E288D | Missense Mutation (SNP) | VAF 22/82 reads (27%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV62128909; called by muse, mutect2
- PTPRA | c.1691T>C p.V564A | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.788); catalogued as COSV99400758; called by muse, mutect2, varscan2
- PWWP2B | c.1222G>A p.V408I | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT tolerated (0.53); PolyPhen benign (0.003); catalogued as rs1231588406, COSV59454024; called by muse, mutect2, varscan2
- PYGM | c.2204G>A p.R735H | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT tolerated (0.11); PolyPhen benign (0.006); catalogued as rs760277933, COSV51215667; called by muse, mutect2, varscan2
- R3HDM2 | c.2389C>G p.P797A | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as COSV100715696; called by muse, mutect2, varscan2
- RADIL | c.3143A>G p.H1048R | Missense Mutation (SNP) | VAF 36/80 reads (45%) | SIFT tolerated (0.41); PolyPhen benign (0.003); catalogued as COSV68203955; called by muse, mutect2
- RANBP10 | c.1457C>T p.T486M | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT tolerated (0.11); PolyPhen benign (0.041); catalogued as rs371532164; called by muse, mutect2, varscan2
- RAPGEF6 | c.1166A>C p.K389T | Missense Mutation (SNP) | VAF 53/130 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV57256222; called by muse, mutect2, varscan2
- RAPH1 | c.2903G>A p.G968E | Missense Mutation (SNP) | VAF 34/82 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.563); catalogued as COSV55583119; called by muse, mutect2, varscan2
- RASGRP3 | c.1750A>G p.R584G (on ENST00000402538 / NM_001349975.2; = p.R583G on NM_015376.2 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 14/24 reads (58%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as COSV67825432; called by muse, mutect2, varscan2
- RBBP4 | c.284C>T p.A95V | Missense Mutation (SNP) | VAF 53/169 reads (31%) | SIFT tolerated (0.15); PolyPhen benign (0.028); catalogued as rs773549765, COSV65132569; called by muse, mutect2, varscan2
- RBM14 | c.2003G>A p.R668H | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as rs1011233354, COSV59559982; called by muse, mutect2, varscan2
- RBM15 | c.358A>G p.S120G | Missense Mutation (SNP) | VAF 9/59 reads (15%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.003); catalogued as COSV100873521; called by muse, mutect2
- RCC1 | c.1093C>T p.R365C | Missense Mutation (SNP) | VAF 53/130 reads (41%) | SIFT tolerated (0.13); PolyPhen benign (0.006); catalogued as rs760969624, COSV65779491; called by muse, mutect2, varscan2
- RCL1 | c.1057G>T p.G353W | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.825); catalogued as COSV67754486; called by muse, mutect2, varscan2
- RCN3 | c.818C>A p.P273H | Missense Mutation (SNP) | VAF 23/54 reads (43%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.575); catalogued as COSV54544048; called by muse, mutect2, varscan2
- REC114 | c.536G>A p.R179Q | Missense Mutation (SNP) | VAF 22/53 reads (42%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as rs778142964, COSV58524925; called by muse, mutect2, varscan2
- RELN | c.257G>A p.G86D | Missense Mutation (SNP) | VAF 24/50 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100633869, COSV59036527; called by muse, mutect2, varscan2
- RERE | c.4019C>T p.A1340V | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0.383); catalogued as COSV61952032; called by muse, mutect2, varscan2
- RETSAT | c.1814C>T p.A605V | Missense Mutation (SNP) | VAF 17/138 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.081); catalogued as COSV99806321; called by muse, mutect2, varscan2
- RFLNB | c.283A>G p.S95G | Missense Mutation (SNP) | VAF 24/76 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs528686861, COSV100225148; called by muse, mutect2
- RGS12 | c.2515C>T p.R839C | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.743); catalogued as rs769613758, COSV58757848; called by muse, mutect2, varscan2
- RGS14 | c.181G>A p.V61M | Missense Mutation (SNP) | VAF 24/46 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs753166092, COSV68772105; called by muse, mutect2, varscan2
- RHBDF2 | c.1861G>T p.G621C | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99166284; called by muse, mutect2, varscan2
- RNF43 | c.1976del p.G659Vfs*41 | Frame Shift Del (DEL) | VAF 30/82 reads (37%) | catalogued as rs755128667, COSV68457540; called by mutect2, varscan2
- ROBO3 | c.743C>T p.A248V | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT tolerated (0.12); PolyPhen benign (0.013); catalogued as COSV67302929; called by muse, mutect2, varscan2
- RPA3 | c.160G>A p.E54K | Missense Mutation (SNP) | VAF 39/101 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as rs1279111309, COSV56190284; called by muse, mutect2, varscan2
- RPL22 | c.44del p.K15Rfs*5 | Frame Shift Del (DEL) | VAF 8/18 reads (44%) | catalogued as rs759765382, COSV52379423; called by mutect2, varscan2
- RTP4 | c.160C>T p.R54W | Missense Mutation (SNP) | VAF 21/54 reads (39%) | SIFT tolerated (0.13); PolyPhen benign (0.017); catalogued as rs756068946, COSV52019020; called by muse, mutect2, varscan2
- RUFY1 | c.622C>T p.R208* | Nonsense Mutation (SNP) | VAF 33/81 reads (41%) | catalogued as rs367832710; called by muse, mutect2, varscan2
- RXRG | c.841G>A p.V281I | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.974); catalogued as rs1416940954, COSV63233254; called by muse, mutect2, varscan2
- RYR1 | c.10651G>A p.E3551K | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT tolerated (0.06); PolyPhen benign (0.3); catalogued as rs753260772, COSV62104342, COSV62114114; called by muse, mutect2, varscan2
- S1PR2 | c.98G>A p.R33H | Missense Mutation (SNP) | VAF 23/34 reads (68%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.803); catalogued as COSV58485980; called by muse, mutect2, varscan2
- SAMD14 | c.855del p.S286Afs*67 (on ENST00000330175 / NM_001257359.2; = p.S314Afs*67 on NM_174920.4) | Frame Shift Del (DEL) | VAF 20/51 reads (39%) | catalogued as rs1567718169; called by mutect2, pindel, varscan2
- SAMD9L | c.1765C>T p.R589* | Nonsense Mutation (SNP) | VAF 20/47 reads (43%) | catalogued as rs763831653, COSV59083491; called by muse, mutect2, varscan2
- SBNO2 | c.4025C>T p.A1342V | Missense Mutation (SNP) | VAF 13/13 reads (100%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.046); catalogued as rs756035925, COSV62324135; called by muse, mutect2, varscan2
- SBNO2 | c.2660C>T p.T887M | Missense Mutation (SNP) | VAF 33/50 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as rs1347743914, COSV62324146; called by muse, mutect2, varscan2
- SCAF11 | c.1759_1760del p.S587Ffs*7 | Frame Shift Del (DEL) | VAF 24/71 reads (34%) | catalogued as rs775617661; called by pindel, varscan2
- SCML1 | c.295A>G p.T99A (on ENST00000380041 / NM_001037540.3; = p.T72A on NM_006746.6) | Missense Mutation (SNP) | VAF 74/175 reads (42%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as COSV101193990; called by muse, mutect2, varscan2
- SCN3B | c.371G>A p.R124Q | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as rs201894537, COSV54801511; called by muse, mutect2, varscan2
- SCYL3 | c.2144A>G p.K715R (on ENST00000367770; = p.K661R on NM_020423.7) | Missense Mutation (SNP) | VAF 24/58 reads (41%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.817); catalogued as COSV53683256; called by muse, mutect2, varscan2
- SDK2 | c.5375C>T p.A1792V | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT tolerated (0.14); PolyPhen benign (0.06); catalogued as rs541836618, COSV66196300; called by muse, mutect2, varscan2
- SEC31A | c.499C>T p.P167S | Missense Mutation (SNP) | VAF 16/31 reads (52%) | SIFT deleterious (0); PolyPhen benign (0.418); catalogued as COSV52352483; called by muse, mutect2, varscan2
- SEMA3B | c.1112G>A p.R371H | Missense Mutation (SNP) | VAF 15/31 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.876); catalogued as COSV100312953; called by muse, mutect2, varscan2
- SERAC1 | c.1232G>A p.R411H | Missense Mutation (SNP) | VAF 35/107 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs139667110; called by muse, mutect2, varscan2
- SETD4 | c.781C>T p.R261C | Missense Mutation (SNP) | VAF 35/88 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.759); catalogued as rs777063951, COSV100145784; called by muse, mutect2, varscan2
- SETDB1 | c.2531A>G p.K844R | Missense Mutation (SNP) | VAF 23/62 reads (37%) | SIFT deleterious (0.04); PolyPhen benign (0.139); catalogued as COSV99645992; called by muse, mutect2, varscan2
- SH3BP2 | c.146G>A p.R49H | Missense Mutation (SNP) | VAF 21/47 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as COSV62555573; called by muse, mutect2, varscan2
- SHTN1 | c.1138C>T p.R380* | Nonsense Mutation (SNP) | VAF 27/63 reads (43%) | catalogued as COSV53379853; called by muse, mutect2, varscan2
- SIN3A | c.3614G>A p.R1205H | Missense Mutation (SNP) | VAF 24/56 reads (43%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.836); catalogued as rs747873220, COSV51238003; called by muse, mutect2, varscan2
- SIRT5 | c.884C>T p.T295M | Missense Mutation (SNP) | VAF 57/163 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.175); catalogued as rs550780850, COSV63081963; called by muse, mutect2, varscan2
- SKA3 | c.460C>T p.R154C | Missense Mutation (SNP) | VAF 76/286 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0.158); catalogued as rs1256196715, COSV53437349; called by muse, mutect2, varscan2
- SKP2 | c.535A>G p.S179G | Missense Mutation (SNP) | VAF 16/62 reads (26%) | SIFT tolerated (0.39); PolyPhen benign (0.001); catalogued as rs752559772, COSV57044793; called by muse, mutect2
- SLAIN2 | c.1105C>T p.R369W | Missense Mutation (SNP) | VAF 18/86 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs745778174, COSV99971910; called by muse, mutect2, varscan2
- SLC12A9 | c.1674dup p.L559Afs*76 | Frame Shift Ins (INS) | VAF 10/32 reads (31%) | catalogued as rs747309463; called by mutect2, varscan2
- SLC15A3 | c.1357G>A p.A453T | Missense Mutation (SNP) | VAF 6/80 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1446418653, COSV99137542; called by muse, mutect2
- SLC17A6 | c.256G>A p.G86S | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV54138800; called by muse, mutect2, varscan2
- SLC23A1 | c.87T>G p.F29L | Missense Mutation (SNP) | VAF 24/75 reads (32%) | SIFT tolerated (0.76); PolyPhen benign (0.003); catalogued as COSV62297757; called by muse, mutect2, varscan2
- SLC23A2 | c.754G>A p.A252T | Missense Mutation (SNP) | VAF 11/23 reads (48%) | SIFT tolerated (0.5); PolyPhen benign (0.007); catalogued as COSV57780503; called by muse, mutect2, varscan2
- SLC2A14 | c.1510G>A p.V504I | Missense Mutation (SNP) | VAF 44/131 reads (34%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as rs1325643887, COSV61588795; called by muse, mutect2, varscan2
- SLC35G3 | c.430G>A p.V144I | Missense Mutation (SNP) | VAF 28/50 reads (56%) | SIFT tolerated (0.88); PolyPhen benign (0); catalogued as rs765407465, COSV52012930; called by muse, mutect2, varscan2
- SLC38A1 | c.247G>A p.A83T | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.35); catalogued as rs1387383265, COSV67064073; called by muse, mutect2, varscan2
- SLC39A8 | c.852del p.E285Sfs*8 | Frame Shift Del (DEL) | VAF 8/29 reads (28%) | catalogued as rs1560527212; called by mutect2, pindel, varscan2
- SLC4A4 | c.2827C>T p.R943C (on ENST00000264485 / NM_001098484.3; = p.R899C on NM_003759.4) | Missense Mutation (SNP) | VAF 30/91 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52623568; called by muse, mutect2, varscan2
- SLC5A11 | c.527A>C p.D176A | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.639); catalogued as COSV61743854; called by muse, mutect2, varscan2
- SLC5A2 | c.1579C>A p.L527I | Missense Mutation (SNP) | VAF 4/37 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100393451; called by mutect2, varscan2
- SLC5A3 | c.1508C>T p.P503L | Missense Mutation (SNP) | VAF 18/42 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs774983348, COSV62967787; called by muse, mutect2, varscan2
- SLC9A1 | c.2341G>A p.A781T | Missense Mutation (SNP) | VAF 19/40 reads (48%) | SIFT tolerated (0.16); PolyPhen benign (0.02); catalogued as rs200843173, COSV56051983; called by muse, mutect2, varscan2
- SLIT3 | c.3487G>A p.V1163M | Missense Mutation (SNP) | VAF 13/27 reads (48%) | SIFT deleterious (0.03); PolyPhen benign (0.161); catalogued as rs748887345, COSV60610673; called by muse, mutect2, varscan2
- SMOC1 | c.833G>A p.R278H | Missense Mutation (SNP) | VAF 11/25 reads (44%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as rs746033223, COSV62760885; called by muse, mutect2, varscan2
- SNED1 | c.2102C>T p.P701L | Missense Mutation (SNP) | VAF 25/49 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs750356654, COSV60022373, COSV60034334; called by muse, mutect2, varscan2
- SNX31 | c.1296del p.F432Lfs*4 | Frame Shift Del (DEL) | VAF 15/106 reads (14%) | catalogued as rs761306337, COSV100310326; called by mutect2, pindel, varscan2
- SORCS1 | c.3188C>T p.T1063M | Missense Mutation (SNP) | VAF 23/65 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.39); catalogued as rs569324090, COSV53909106; called by muse, mutect2, varscan2
- SOS2 | c.1354G>A p.G452S | Missense Mutation (SNP) | VAF 40/126 reads (32%) | SIFT tolerated (0.16); PolyPhen benign (0.23); catalogued as rs1272261716, COSV53575439; called by muse, mutect2, varscan2
- SPA17 | c.199C>T p.R67C | Missense Mutation (SNP) | VAF 36/90 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs925623136, COSV57033352; called by muse, mutect2, varscan2
- SPAG17 | c.818_820del p.L273del | In Frame Del (DEL) | VAF 28/90 reads (31%) | catalogued as rs747449705; called by pindel, varscan2
- SPAST | c.1245C>T p.Y415= | Splice Region (SNP) | VAF 25/73 reads (34%) | catalogued as rs762514549, CD090389, COSV59517563; called by muse, mutect2, varscan2
- STAB1 | c.6671C>T p.S2224L | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.36); catalogued as rs763882360, COSV58743783; called by muse, mutect2, varscan2
- SULF2 | c.847C>T p.R283C | Missense Mutation (SNP) | VAF 41/113 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV63420414; called by muse, mutect2, varscan2
- SULT1A1 | c.214C>T p.R72* | Nonsense Mutation (SNP) | VAF 25/89 reads (28%) | catalogued as rs141343888; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SYAP1 | c.920C>T p.A307V | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as COSV66467889; called by muse, mutect2, varscan2
- SYNE1 | c.25453C>T p.L8485F (on ENST00000367255 / NM_182961.4; = p.L8437F on NM_033071.3) | Missense Mutation (SNP) | VAF 16/51 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV55117702; called by muse, mutect2, varscan2
- SYNE2 | c.6472C>T p.L2158F | Missense Mutation (SNP) | VAF 39/130 reads (30%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.976); catalogued as COSV59972303; called by muse, mutect2, varscan2
- TACC3 | c.1090A>G p.K364E | Missense Mutation (SNP) | VAF 16/78 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.3); catalogued as COSV57608336; called by muse, mutect2, varscan2
- TAF11 | c.65C>T p.A22V | Missense Mutation (SNP) | VAF 18/42 reads (43%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as COSV63543374; called by muse, mutect2, varscan2
- TAF1C | c.22C>T p.R8C | Missense Mutation (SNP) | VAF 15/34 reads (44%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.804); catalogued as rs747153539, COSV58989663; called by muse, mutect2, varscan2
- TASOR2 | c.5428C>A p.L1810I | Missense Mutation (SNP) | VAF 23/50 reads (46%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.638); catalogued as COSV60169855; called by muse, mutect2, varscan2
- TBC1D9B | c.3262G>A p.A1088T (on ENST00000356834 / NM_198868.3; = p.A1071T on NM_015043.4) | Missense Mutation (SNP) | VAF 18/36 reads (50%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as COSV62284231; called by muse, mutect2, varscan2
- TBX20 | c.350G>T p.G117V | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs138597530; called by muse, mutect2, varscan2
- TBX5 | c.310A>G p.M104V | Missense Mutation (SNP) | VAF 31/83 reads (37%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.989); catalogued as COSV59864970, COSV59865934; called by muse, mutect2, varscan2
- TDRD10 | c.321G>C p.R107S | Missense Mutation (SNP) | VAF 20/54 reads (37%) | SIFT tolerated (0.42); PolyPhen benign (0.007); catalogued as rs1482283379, COSV63813651, COSV63813915; called by muse, varscan2
- TECPR2 | c.3451G>A p.V1151I | Missense Mutation (SNP) | VAF 16/28 reads (57%) | SIFT tolerated (0.38); PolyPhen benign (0.001); catalogued as rs773240218, COSV63974630; called by muse, mutect2, varscan2
- TFB1M | c.1021G>A p.A341T | Missense Mutation (SNP) | VAF 71/220 reads (32%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as rs149125723; called by muse, mutect2, varscan2
- TG | c.4798G>A p.V1600M | Missense Mutation (SNP) | VAF 19/67 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.036); catalogued as rs145098737; called by muse, mutect2, varscan2
- THBS1 | c.3229C>T p.R1077W | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52950625; called by muse, mutect2, varscan2
- THOC5 | c.569G>A p.R190H | Missense Mutation (SNP) | VAF 18/42 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1045252108, COSV63801463; called by muse, mutect2, varscan2
- TIE1 | c.2105G>T p.S702I | Missense Mutation (SNP) | VAF 17/42 reads (40%) | SIFT tolerated (0.52); PolyPhen benign (0.224); catalogued as COSV65251634; called by muse, mutect2, varscan2
- TIGIT | c.251G>A p.R84Q | Missense Mutation (SNP) | VAF 18/38 reads (47%) | SIFT tolerated (0.06); PolyPhen benign (0.288); catalogued as rs1351685650, COSV67329620; called by muse, mutect2, varscan2
- TIRAP | c.644G>A p.R215H | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as rs185114125; called by muse, mutect2, varscan2
- TJP3 | c.1742G>A p.R581H | Missense Mutation (SNP) | VAF 17/22 reads (77%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs373394367, COSV53665990; called by muse, mutect2, varscan2
- TLCD4 | c.559G>A p.V187M | Missense Mutation (SNP) | VAF 75/160 reads (47%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.92); catalogued as rs995809602, COSV64633685; called by muse, mutect2, varscan2
- TMCO3 | c.1895G>A p.R632Q | Missense Mutation (SNP) | VAF 36/81 reads (44%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.624); catalogued as rs200795081, COSV64808957; called by muse, mutect2, varscan2
- TMEM132D | c.1733G>A p.R578Q | Missense Mutation (SNP) | VAF 22/50 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as rs774723649, COSV67162763; called by muse, mutect2, varscan2
- TMEM175 | c.103C>T p.R35C | Missense Mutation (SNP) | VAF 17/43 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs542936413, COSV53281522; called by muse, mutect2, varscan2
- TMEM183A | c.560G>A p.R187H | Missense Mutation (SNP) | VAF 18/51 reads (35%) | SIFT tolerated (0.08); PolyPhen benign (0.091); catalogued as COSV65888272; called by muse, mutect2, varscan2
- TMEM245 | c.916G>A p.E306K | Missense Mutation (SNP) | VAF 36/81 reads (44%) | SIFT tolerated (0.26); PolyPhen benign (0.109); catalogued as COSV65824684; called by muse, mutect2, varscan2
- TMEM79 | c.824G>A p.R275Q | Missense Mutation (SNP) | VAF 23/56 reads (41%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.963); catalogued as rs563432840, COSV55297103; called by muse, mutect2, varscan2
- TMOD1 | c.991G>A p.A331T | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.851); catalogued as rs753776204, COSV52246463; called by muse, mutect2, varscan2
- TMPO | c.295del p.T99Lfs*12 | Frame Shift Del (DEL) | VAF 30/78 reads (38%) | catalogued as rs770800449; called by mutect2, varscan2
- TMPRSS7 | c.1847dup p.W617Lfs*71 (on ENST00000452346; = p.W491Lfs*71 on NM_001042575.2) | Frame Shift Ins (INS) | VAF 14/71 reads (20%) | catalogued as rs1264400778; called by mutect2, pindel, varscan2
- TNC | c.3760G>T p.E1254* | Nonsense Mutation (SNP) | VAF 23/48 reads (48%) | catalogued as COSV60781322, COSV60791155; called by muse, mutect2, varscan2
- TNFAIP2 | c.218A>T p.D73V | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.082); catalogued as COSV60696432; called by muse, mutect2, varscan2
- TNFRSF1A | c.68A>G p.Y23C | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.87); catalogued as COSV50830033; called by muse, mutect2, varscan2
- TNFSF8 | c.556G>A p.V186I | Missense Mutation (SNP) | VAF 69/188 reads (37%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs145748228; called by muse, mutect2, varscan2
- TNK2 | c.790G>A p.D264N | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT tolerated (0.25); PolyPhen benign (0.029); catalogued as rs1434082281, COSV57376908; called by muse, varscan2
- TPCN1 | c.875G>A p.R292Q | Missense Mutation (SNP) | VAF 20/45 reads (44%) | SIFT tolerated (0.45); PolyPhen benign (0.081); catalogued as COSV59232854; called by muse, mutect2, varscan2
- TPR | c.1887T>C p.H629= | Splice Region (SNP) | VAF 16/39 reads (41%) | catalogued as COSV66605469; called by muse, mutect2
- TRANK1 | c.5080G>A p.V1694I | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.335); catalogued as rs772194630, COSV57142866; called by muse, mutect2, varscan2
- TRANK1 | c.2849G>A p.R950H | Missense Mutation (SNP) | VAF 36/86 reads (42%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.959); catalogued as rs765403445, COSV100085015; called by muse, mutect2, varscan2
- TRIM35 | c.1045C>T p.R349C | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as rs748368431, COSV59523840; called by muse, mutect2, varscan2
- TRIM42 | c.1760G>A p.S587N | Missense Mutation (SNP) | VAF 24/40 reads (60%) | SIFT tolerated (0.53); PolyPhen benign (0.035); catalogued as rs774721963, COSV53887319; called by muse, mutect2, varscan2
- TRIM58 | c.124G>A p.E42K | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT tolerated (0.32); PolyPhen benign (0.069); catalogued as COSV63572483; called by muse, mutect2, varscan2
- TRMT6 | c.578C>T p.T193M | Missense Mutation (SNP) | VAF 31/66 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs766405213, COSV52542704; called by muse, mutect2, varscan2
- TSPAN3 | c.238C>T p.R80C | Missense Mutation (SNP) | VAF 25/56 reads (45%) | SIFT tolerated (0.16); PolyPhen benign (0.082); catalogued as rs376931567; called by muse, mutect2, varscan2
- TSPYL4 | c.413del p.G138Afs*6 | Frame Shift Del (DEL) | VAF 7/37 reads (19%) | catalogued as rs1459456305; called by mutect2, pindel, varscan2
- TTC26 | c.238T>C p.Y80H | Missense Mutation (SNP) | VAF 35/87 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); catalogued as COSV58274840; called by muse, mutect2, varscan2
- TTLL8 | c.1954C>T p.R652W | Missense Mutation (SNP) | VAF 17/29 reads (59%) | SIFT deleterious (0); PolyPhen possibly damaging (0.548); catalogued as COSV99838704; called by muse, mutect2, varscan2
- TTN | c.99410C>T p.T33137M (on ENST00000591111; = p.T25713M on NM_003319.4) | Missense Mutation (SNP) | VAF 6/50 reads (12%) | PolyPhen benign (0.337); catalogued as rs762158917, COSV60382196; ClinVar: uncertain significance; called by mutect2, varscan2
- TUT7 | c.2842dup p.Y948Lfs*2 | Frame Shift Ins (INS) | VAF 42/138 reads (30%) | catalogued as rs751076382; called by mutect2, varscan2
- UACA | c.1030G>A p.E344K | Missense Mutation (SNP) | VAF 69/163 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1306315355, COSV100537835; called by muse, mutect2, varscan2
- UBAP2 | c.1948C>T p.R650* | Nonsense Mutation (SNP) | VAF 26/58 reads (45%) | catalogued as rs1407980677, COSV62549266; called by muse, mutect2, varscan2
- UBASH3A | c.1423A>G p.I475V | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT tolerated (0.56); PolyPhen benign (0.003); catalogued as COSV52316533; called by muse, mutect2, varscan2
- UBE2W | c.397C>T p.R133* | Nonsense Mutation (SNP) | VAF 88/221 reads (40%) | catalogued as rs1373683191, COSV62480140; called by muse, mutect2, varscan2
- UNC13C | c.790C>T p.R264* | Nonsense Mutation (SNP) | VAF 20/38 reads (53%) | catalogued as COSV52897945; called by muse, mutect2, varscan2
- UPF1 | c.763C>T p.R255C | Missense Mutation (SNP) | VAF 15/30 reads (50%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.732); catalogued as COSV53202527; called by muse, mutect2, varscan2
- URGCP | c.923C>T p.S308L (on ENST00000453200 / NM_001077663.3; = p.S299L on NM_017920.4) | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.336); catalogued as COSV56253324; called by muse, mutect2, varscan2
- UROD | c.95C>T p.P32L | Missense Mutation (SNP) | VAF 25/59 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55802148; called by muse, mutect2, varscan2
- USP13 | c.772G>A p.V258M | Missense Mutation (SNP) | VAF 24/60 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs144601583; called by muse, mutect2, varscan2
- USP34 | c.632G>A p.R211H | Missense Mutation (SNP) | VAF 74/186 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.375); catalogued as rs765394497, COSV68403975; called by muse, mutect2, varscan2
- USP35 | c.1962del p.T655Pfs*23 | Frame Shift Del (DEL) | VAF 20/56 reads (36%) | catalogued as rs764735138; called by mutect2, varscan2
- USP35 | c.3037T>G p.F1013V | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.344); catalogued as COSV60871414; called by muse, mutect2
- UVRAG | c.1154C>A p.P385H | Missense Mutation (SNP) | VAF 51/118 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV100638681; called by muse, mutect2, varscan2
- VDAC1 | c.487C>T p.R163* | Nonsense Mutation (SNP) | VAF 33/78 reads (42%) | catalogued as COSV54738636, COSV99527351; called by muse, mutect2, varscan2
- VPS13A | c.2326C>T p.R776* | Nonsense Mutation (SNP) | VAF 14/128 reads (11%) | catalogued as rs1417246536, COSV62440130; called by muse, mutect2, varscan2
- VPS9D1 | c.1535C>T p.A512V | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs769008409, COSV66995038; called by muse, mutect2, varscan2
- VWF | c.3199G>A p.V1067I | Missense Mutation (SNP) | VAF 57/165 reads (35%) | SIFT tolerated (0.6); PolyPhen benign (0.001); catalogued as rs749872924, COSV54636143; called by muse, mutect2, varscan2
- WBP11 | c.1895C>A p.A632D | Missense Mutation (SNP) | VAF 24/53 reads (45%) | SIFT tolerated (0.33); PolyPhen probably damaging (0.991); catalogued as COSV53765008; called by muse, mutect2, varscan2
- WBP11 | c.1454G>A p.R485H | Missense Mutation (SNP) | VAF 28/79 reads (35%) | SIFT tolerated, low confidence (0.55); PolyPhen probably damaging (0.98); catalogued as COSV53765029; called by muse, mutect2, varscan2
- WDR48 | c.668C>T p.T223M | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs576224342, COSV56534661; called by muse, mutect2, varscan2
- WFIKKN1 | c.428C>T p.A143V | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV50193451; called by muse, mutect2, varscan2
- WNK2 | c.1603C>T p.R535C | Missense Mutation (SNP) | VAF 28/73 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52954652; called by muse, mutect2, varscan2
- WNT11 | c.541dup p.T181Nfs*7 | Frame Shift Ins (INS) | VAF 24/72 reads (33%) | catalogued as rs1320348614; called by mutect2, varscan2
- WRAP53 | c.1565del p.A522Gfs*26 | Frame Shift Del (DEL) | VAF 30/40 reads (75%) | catalogued as rs373064567, COSV56832921, COSV56833408; called by mutect2, varscan2
- WWC3 | c.2717G>A p.R906H | Missense Mutation (SNP) | VAF 24/56 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66508237; called by muse, mutect2, varscan2
- XIRP1 | c.923G>A p.R308H | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.156); catalogued as rs751411277, COSV61141733; called by muse, mutect2, varscan2
- XRCC3 | c.113T>C p.L38P | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.851); catalogued as rs758434542, COSV100721355; called by muse, mutect2, varscan2
- YTHDC1 | c.1660C>T p.P554S (on ENST00000344157 / NM_001031732.4; = p.P536S on NM_133370.4) | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.115); catalogued as COSV60012332; called by muse, mutect2, varscan2
- ZBTB7C | c.394del p.D132Tfs*90 | Frame Shift Del (DEL) | VAF 32/84 reads (38%) | catalogued as COSV59691020; called by mutect2, pindel, varscan2
- ZC3H18 | c.2037dup p.R680Qfs*14 | Frame Shift Ins (INS) | VAF 16/40 reads (40%) | catalogued as rs751577786; called by mutect2, varscan2
- ZDBF2 | c.2998del p.T1000Qfs*3 | Frame Shift Del (DEL) | VAF 12/82 reads (15%) | catalogued as rs1559154594; called by mutect2, pindel, varscan2
- ZEB2 | c.3269C>T p.A1090V | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.051); catalogued as COSV100357064; called by muse, mutect2, varscan2
- ZFAT | c.2243-3del | Splice Region (DEL) | VAF 10/39 reads (26%) | catalogued as rs35184160; called by mutect2, pindel
- ZFHX3 | c.3758G>A p.R1253H | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.924); catalogued as rs370933867; called by muse, mutect2, varscan2
- ZFHX4 | c.10011G>T p.Q3337H | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.995); catalogued as COSV51499080; called by muse, mutect2
- ZIC1 | c.1273T>C p.S425P | Missense Mutation (SNP) | VAF 43/100 reads (43%) | SIFT tolerated (0.32); PolyPhen benign (0.031); catalogued as rs75992939, COSV51551599; called by muse, mutect2, varscan2
- ZIM2 | c.1510G>A p.G504S | Missense Mutation (SNP) | VAF 20/43 reads (47%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs138640675; called by muse, mutect2, varscan2
- ZKSCAN4 | c.1624del p.T542Lfs*27 | Frame Shift Del (DEL) | VAF 7/61 reads (11%) | catalogued as rs757603403; called by mutect2, pindel, varscan2
- ZMYND15 | c.179A>G p.H60R | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.983); catalogued as COSV99351890; called by muse, mutect2
- ZMYND8 | c.3085G>A p.A1029T (on ENST00000311275 / NM_001363741.2; = p.A1003T on NM_012408.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 23/49 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs868705075, COSV53695367, COSV99521212; called by muse, mutect2, varscan2
- ZNF165 | c.76G>T p.E26* | Nonsense Mutation (SNP) | VAF 40/88 reads (45%) | catalogued as COSV66103036; called by muse, mutect2, varscan2
- ZNF214 | c.1320A>C p.K440N | Missense Mutation (SNP) | VAF 15/54 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV53482776, COSV99547699; called by muse, mutect2, varscan2
- ZNF221 | c.39_40del p.C14Qfs*4 | Frame Shift Del (DEL) | VAF 40/132 reads (30%) | catalogued as rs780956282; called by pindel, varscan2
- ZNF28 | c.1526G>A p.C509Y | Missense Mutation (SNP) | VAF 7/66 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs1255926344, COSV60425768; called by muse, mutect2, varscan2
- ZNF318 | c.1573C>T p.R525* | Nonsense Mutation (SNP) | VAF 24/121 reads (20%) | catalogued as rs780673816, COSV58934882; called by muse, mutect2, varscan2
- ZNF423 | c.1199G>A p.R400Q (on ENST00000563137 / NM_001379286.1; = p.R392Q on NM_015069.4) | Missense Mutation (SNP) | VAF 28/54 reads (52%) | SIFT tolerated (0.33); PolyPhen benign (0.018); catalogued as rs574135774, COSV52179386, COSV99280040; called by muse, mutect2, varscan2
- ZNF440 | c.1045T>C p.F349L | Missense Mutation (SNP) | VAF 46/66 reads (70%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.494); catalogued as COSV58372702; called by muse, mutect2, varscan2
- ZNF549 | c.1627del p.R543Dfs*94 (on ENST00000376233 / NM_001199295.2; = p.R530Dfs*94 on NM_153263.2) | Frame Shift Del (DEL) | VAF 10/84 reads (12%) | catalogued as rs1438832761; called by mutect2, pindel, varscan2
- ZNF618 | c.316G>A p.V106I | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.381); catalogued as rs1358629363, COSV55930727; called by muse, mutect2, varscan2
- ZNF618 | c.1282C>T p.R428* (on ENST00000374126 / NM_001318042.2; = p.R335* on NM_133374.2) | Nonsense Mutation (SNP) | VAF 8/40 reads (20%) | catalogued as COSV55918391; called by muse, mutect2, varscan2
- ZNF638 | c.1841G>A p.S614N | Missense Mutation (SNP) | VAF 24/262 reads (9%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.968); catalogued as COSV100040180; called by muse, mutect2
- ZNF648 | c.1052G>A p.R351H | Missense Mutation (SNP) | VAF 18/55 reads (33%) | SIFT tolerated (0.31); PolyPhen benign (0.046); catalogued as rs1202781371, COSV60572989; called by muse, mutect2, varscan2
- ZNF692 | c.320A>C p.D107A | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT tolerated (0.36); PolyPhen benign (0.039); catalogued as rs1292657399, COSV60660396; called by muse, mutect2, varscan2
- ZNF696 | c.673G>A p.A225T | Missense Mutation (SNP) | VAF 8/13 reads (62%) | SIFT tolerated (0.57); PolyPhen benign (0.01); catalogued as rs756234415, COSV57525959; called by muse, mutect2, varscan2
- ZNF777 | c.2411G>A p.R804Q | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.727); catalogued as rs1485732253, COSV99925424; called by muse, mutect2, varscan2
- ZNF804B | c.2270G>A p.C757Y | Missense Mutation (SNP) | VAF 35/83 reads (42%) | SIFT tolerated (0.13); PolyPhen benign (0.015); catalogued as rs201715882, COSV60858265; called by muse, mutect2, varscan2
- ZNF862 | c.521G>A p.R174Q | Missense Mutation (SNP) | VAF 15/32 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.616); catalogued as rs911327138, COSV56226497; called by muse, mutect2, varscan2
- ABCC12 | c.3221_3222dup p.R1075Cfs*54 | Frame Shift Ins (INS) | VAF 15/40 reads (38%) | called by mutect2, varscan2
- ACACA | c.6596dup p.E2200Gfs*26 | Frame Shift Ins (INS) | VAF 38/106 reads (36%) | called by mutect2, pindel, varscan2
- ADCY5 | c.2456dup p.L820Tfs*74 | Frame Shift Ins (INS) | VAF 38/138 reads (28%) | called by mutect2, pindel, varscan2
- ADGRB2 | c.3018_3020del p.F1007del | In Frame Del (DEL) | VAF 18/58 reads (31%) | called by pindel, varscan2
- AGAP1 | c.743del p.N248Ifs*28 | Frame Shift Del (DEL) | VAF 20/56 reads (36%) | called by mutect2, pindel, varscan2
- ALG10 | c.886dup p.S296Ffs*15 | Frame Shift Ins (INS) | VAF 136/379 reads (36%) | called by mutect2, varscan2
- AMOTL1 | c.1000del p.Y334Mfs*22 | Frame Shift Del (DEL) | VAF 8/26 reads (31%) | called by mutect2, varscan2
- ANKRD17 | c.2657del p.K886Sfs*4 | Frame Shift Del (DEL) | VAF 102/268 reads (38%) | called by mutect2, varscan2
- APOBEC4 | c.729_731del p.L244del | In Frame Del (DEL) | VAF 112/300 reads (37%) | called by pindel, varscan2
- ARAF | c.763del p.R255Gfs*37 | Frame Shift Del (DEL) | VAF 8/22 reads (36%) | called by mutect2, pindel, varscan2
- ATAD5 | c.4408dup p.S1470Ffs*4 | Frame Shift Ins (INS) | VAF 78/220 reads (35%) | called by mutect2, pindel, varscan2
- ATP13A3 | c.1785dup p.Q596Tfs*5 | Frame Shift Ins (INS) | VAF 28/91 reads (31%) | called by pindel, varscan2
- ATP9B | c.1103dup p.N368Kfs*2 | Frame Shift Ins (INS) | VAF 34/111 reads (31%) | called by mutect2, pindel, varscan2
- B3GALT2 | c.458del p.L153* | Frame Shift Del (DEL) | VAF 30/70 reads (43%) | called by mutect2, varscan2
- C5orf22 | c.450dup p.P151Tfs*13 | Frame Shift Ins (INS) | VAF 39/119 reads (33%) | called by mutect2, pindel, varscan2
- CDK12 | c.2048del p.P683Qfs*70 | Frame Shift Del (DEL) | VAF 23/78 reads (29%) | called by mutect2, pindel, varscan2
- CEBPE | c.486del p.G163Afs*22 | Frame Shift Del (DEL) | VAF 9/34 reads (26%) | called by mutect2, pindel
- CEND1 | c.330del p.P111Lfs*26 | Frame Shift Del (DEL) | VAF 9/38 reads (24%) | called by mutect2, pindel, varscan2
- CEP83 | c.1852dup p.R618Kfs*10 | Frame Shift Ins (INS) | VAF 33/106 reads (31%) | called by mutect2, pindel, varscan2
- CHD7 | c.8962del p.D2988Mfs*3 | Frame Shift Del (DEL) | VAF 24/70 reads (34%) | called by mutect2, varscan2
- CLEC16A | c.1832del p.L611Wfs*11 | Frame Shift Del (DEL) | VAF 10/31 reads (32%) | called by mutect2, pindel, varscan2
- CMTM8 | c.259T>G p.F87V | Missense Mutation (SNP) | VAF 10/113 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.676); called by muse, mutect2
- CSF3 | c.97del p.L33Wfs*16 | Frame Shift Del (DEL) | VAF 8/23 reads (35%) | called by mutect2, pindel, varscan2
- CSPG4 | c.734del p.G245Afs*98 | Frame Shift Del (DEL) | VAF 8/56 reads (14%) | called by mutect2, pindel
- CTCF | c.579dup p.D194Rfs*36 | Frame Shift Ins (INS) | VAF 46/147 reads (31%) | called by mutect2, pindel, varscan2
- CUX2 | c.619dup p.I207Nfs*32 | Frame Shift Ins (INS) | VAF 9/26 reads (35%) | called by mutect2, pindel, varscan2
- CWC27 | c.756dup p.G253Rfs*2 | Frame Shift Ins (INS) | VAF 69/294 reads (23%) | called by mutect2, pindel, varscan2
- DHX29 | c.758_762del p.E253Gfs*5 | Frame Shift Del (DEL) | VAF 61/157 reads (39%) | called by mutect2, pindel, varscan2
- DNAI3 | c.1956del p.D653Tfs*13 | Frame Shift Del (DEL) | VAF 49/218 reads (22%) | called by mutect2, pindel, varscan2
- DNM2 | c.1928_1930del p.F643del (on ENST00000355667 / NM_001005360.3; = p.F639del on NM_004945.3) | In Frame Del (DEL) | VAF 15/17 reads (88%) | called by mutect2, varscan2
- DNMT3B | c.561del p.Y188Tfs*4 | Frame Shift Del (DEL) | VAF 14/51 reads (27%) | called by mutect2, pindel, varscan2
- EGR3 | c.520del p.Q174Rfs*17 | Frame Shift Del (DEL) | VAF 30/98 reads (31%) | called by mutect2, pindel, varscan2
- FABP2 | c.64dup p.M22Nfs*4 | Frame Shift Ins (INS) | VAF 33/110 reads (30%) | called by mutect2, pindel, varscan2
- FAM71B | c.1613del p.L538* | Frame Shift Del (DEL) | VAF 62/175 reads (35%) | called by mutect2, pindel, varscan2
- FASTKD3 | c.853del p.L285Yfs*3 | Frame Shift Del (DEL) | VAF 6/44 reads (14%) | called by mutect2, pindel, varscan2
- FBXW7 | c.2001del p.S668Vfs*39 (on ENST00000281708 / NM_001349798.2; = p.S588Vfs*39 on NM_018315.5) | Frame Shift Del (DEL) | VAF 42/121 reads (35%) | called by mutect2, pindel, varscan2
- FGFR1 | c.578dup p.N193Kfs*8 (on ENST00000447712 / NM_023110.3; = p.N191Kfs*8 on NM_015850.4 and 1 other RefSeq transcript) | Frame Shift Ins (INS) | VAF 68/189 reads (36%) | called by mutect2, pindel, varscan2
- FMNL3 | c.45del p.S16Lfs*27 | Frame Shift Del (DEL) | VAF 6/31 reads (19%) | called by mutect2, pindel, varscan2
- GCNT1 | c.913dup p.I305Nfs*15 | Frame Shift Ins (INS) | VAF 37/92 reads (40%) | called by mutect2, pindel, varscan2
- GGN | c.1705del p.A569Pfs*47 | Frame Shift Del (DEL) | VAF 15/41 reads (37%) | called by mutect2, pindel, varscan2
- GPR19 | c.1109dup p.N370Kfs*22 | Frame Shift Ins (INS) | VAF 54/163 reads (33%) | called by mutect2, varscan2
- GRAMD1B | c.2085dup p.W696Mfs*13 | Frame Shift Ins (INS) | VAF 6/18 reads (33%) | called by mutect2, pindel, varscan2
- GRIN2B | c.99del p.S34Afs*38 | Frame Shift Del (DEL) | VAF 5/19 reads (26%) | called by mutect2, pindel
- GRK2 | c.1559_1561del p.E520del | In Frame Del (DEL) | VAF 20/46 reads (43%) | called by pindel, varscan2
- HEY1 | c.768_770del p.S257del | In Frame Del (DEL) | VAF 32/93 reads (34%) | called by pindel, varscan2
- HOXD3 | c.678_679del p.E226Dfs*38 | Frame Shift Del (DEL) | VAF 21/73 reads (29%) | called by pindel, varscan2
- HR | c.518del p.P173Qfs*9 | Frame Shift Del (DEL) | VAF 28/73 reads (38%) | called by mutect2, pindel, varscan2
- HSPH1 | c.65del p.G22Afs*66 | Frame Shift Del (DEL) | VAF 22/61 reads (36%) | called by mutect2, pindel, varscan2
- IGKV2-24 | c.202C>A p.P68T | Missense Mutation (SNP) | VAF 82/234 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- IGLC7 | c.199G>C p.A67P | Missense Mutation (SNP) | VAF 85/188 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- KANSL1 | c.1311del p.K437Nfs*43 | Frame Shift Del (DEL) | VAF 17/53 reads (32%) | called by mutect2, pindel, varscan2
- KANSL3 | c.955del p.V319* | Frame Shift Del (DEL) | VAF 19/54 reads (35%) | called by mutect2, pindel, varscan2
- L3MBTL1 | c.548del p.P183Qfs*39 (on ENST00000418998 / NM_001377303.1; = p.P93Qfs*39 on NM_015478.7) | Frame Shift Del (DEL) | VAF 20/50 reads (40%) | called by mutect2, pindel, varscan2
- LARP4B | c.2010dup p.E671Rfs*105 | Frame Shift Ins (INS) | VAF 35/85 reads (41%) | called by mutect2, pindel, varscan2
- LCOR | c.1295dup p.N432Kfs*7 | Frame Shift Ins (INS) | VAF 12/30 reads (40%) | called by mutect2, pindel
- MATR3 | c.708del p.F236Lfs*176 | Frame Shift Del (DEL) | VAF 20/51 reads (39%) | called by mutect2, pindel, varscan2
- MINDY3 | c.902dup p.E302* | Frame Shift Ins (INS) | VAF 17/49 reads (35%) | called by mutect2, pindel, varscan2
- MLF2 | c.475dup p.D159Gfs*28 | Frame Shift Ins (INS) | VAF 8/33 reads (24%) | called by mutect2, pindel, varscan2
- MTMR2 | c.1884_1885dup p.A629Efs*20 | Frame Shift Ins (INS) | VAF 39/121 reads (32%) | called by mutect2, varscan2
- MUC5B | c.10250del p.P3417Qfs*3 | Frame Shift Del (DEL) | VAF 152/442 reads (34%) | called by mutect2, pindel, varscan2
- MZF1 | c.563_564del p.E188Gfs*26 | Frame Shift Del (DEL) | VAF 20/67 reads (30%) | called by pindel, varscan2
- NACC2 | c.89G>A p.C30Y | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NARF | c.725del p.P242Lfs*13 | Frame Shift Del (DEL) | VAF 10/25 reads (40%) | called by mutect2, pindel, varscan2
- NCOR2 | c.2925del p.I976Sfs*87 | Frame Shift Del (DEL) | VAF 16/39 reads (41%) | called by mutect2, pindel, varscan2
- NEB | c.1622del p.P541Lfs*16 | Frame Shift Del (DEL) | VAF 45/108 reads (42%) | called by mutect2, pindel, varscan2
- NFE2L1 | c.485del p.P162Qfs*6 | Frame Shift Del (DEL) | VAF 9/39 reads (23%) | called by mutect2, pindel, varscan2
- NIPBL | c.2843del p.G948Afs*6 | Frame Shift Del (DEL) | VAF 23/109 reads (21%) | called by mutect2, pindel, varscan2
- NOC4L | c.1142del p.P381Lfs*103 | Frame Shift Del (DEL) | VAF 12/39 reads (31%) | called by mutect2, pindel, varscan2
- NOCT | c.520_522del p.E174del | In Frame Del (DEL) | VAF 6/37 reads (16%) | called by pindel, varscan2
- NRIP1 | c.2184dup p.E729Rfs*8 | Frame Shift Ins (INS) | VAF 18/58 reads (31%) | called by mutect2, varscan2
- NYNRIN | c.1876del p.Q626Rfs*7 | Frame Shift Del (DEL) | VAF 7/21 reads (33%) | called by mutect2, pindel, varscan2
- OGDH | c.2847dup p.N950Qfs*3 | Frame Shift Ins (INS) | VAF 6/24 reads (25%) | called by mutect2, pindel, varscan2
- OSGEPL1 | c.419del p.K140Sfs*18 | Frame Shift Del (DEL) | VAF 36/93 reads (39%) | called by mutect2, varscan2
- OSR2 | c.171del p.Y58Ifs*79 | Frame Shift Del (DEL) | VAF 9/25 reads (36%) | called by mutect2, pindel, varscan2
- P2RX4 | c.667del p.T223Qfs*13 | Frame Shift Del (DEL) | VAF 19/62 reads (31%) | called by mutect2, pindel, varscan2
- PCDHGC3 | c.1668del p.F556Lfs*34 | Frame Shift Del (DEL) | VAF 4/20 reads (20%) | called by mutect2, pindel
- PDE9A | c.1742_1743dup p.S582Efs*5 | Frame Shift Ins (INS) | VAF 14/36 reads (39%) | called by mutect2, varscan2
- PGC | c.1093del p.D365Mfs*18 | Frame Shift Del (DEL) | VAF 9/34 reads (26%) | called by mutect2, pindel, varscan2
- PIGB | c.41del p.G14Afs*19 | Frame Shift Del (DEL) | VAF 7/28 reads (25%) | called by mutect2, pindel
- POSTN | c.1623del p.F541Lfs*4 | Frame Shift Del (DEL) | VAF 29/86 reads (34%) | called by mutect2, pindel, varscan2
- PPIG | c.36del p.F12Lfs*115 | Frame Shift Del (DEL) | VAF 44/110 reads (40%) | called by mutect2, pindel, varscan2
- PRKCA | c.1762del p.E588Rfs*4 | Frame Shift Del (DEL) | VAF 8/20 reads (40%) | called by mutect2, pindel, varscan2
- PRKCSH | c.784_785del p.Q262Dfs*34 | Frame Shift Del (DEL) | VAF 27/46 reads (59%) | called by pindel, varscan2
- PROCA1 | c.558del p.I187Sfs*14 (on ENST00000439862 / NM_001366301.1; = p.I159Sfs*14 on NM_152465.3 and 2 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 8/22 reads (36%) | called by mutect2, pindel, varscan2
- PTCHD4 | c.280del p.L94Wfs*21 | Frame Shift Del (DEL) | VAF 12/36 reads (33%) | called by mutect2, pindel, varscan2
- PTPRK | c.2741dup p.N914Kfs*10 (on ENST00000368215 / NM_001291984.2; = p.N915Kfs*10 on NM_002844.4) | Frame Shift Ins (INS) | VAF 23/208 reads (11%) | called by mutect2, pindel, varscan2
- RAB6B | c.14del p.G5Efs*7 | Frame Shift Del (DEL) | VAF 12/39 reads (31%) | called by mutect2, pindel, varscan2
- RAD17 | c.152dup p.N51Kfs*37 (on ENST00000380774 / NM_133339.2; = p.N40Kfs*37 on NM_002873.1) | Frame Shift Ins (INS) | VAF 70/185 reads (38%) | called by mutect2, pindel, varscan2
- RFX5 | c.56del p.P19Qfs*28 | Frame Shift Del (DEL) | VAF 15/42 reads (36%) | called by mutect2, pindel, varscan2
- RNF207 | c.1150del p.H384Tfs*6 | Frame Shift Del (DEL) | VAF 23/51 reads (45%) | called by mutect2, pindel, varscan2
- RTCA | c.494del p.G165Vfs*4 | Frame Shift Del (DEL) | VAF 50/150 reads (33%) | called by mutect2, pindel, varscan2
- RTCB | c.736del p.M246Wfs*11 | Frame Shift Del (DEL) | VAF 36/86 reads (42%) | called by mutect2, varscan2
- SBNO1 | c.3416dup p.N1139Kfs*5 (on ENST00000420886; = p.N1138Kfs*5 on NM_018183.5) | Frame Shift Ins (INS) | VAF 32/120 reads (27%) | called by mutect2, varscan2
- SCAF4 | c.1955_1956dup p.E653Qfs*24 | Frame Shift Ins (INS) | VAF 54/148 reads (36%) | called by mutect2, varscan2
- SCRN1 | c.1216_1217del p.V406* | Frame Shift Del (DEL) | VAF 19/62 reads (31%) | called by pindel, varscan2
- SEC23IP | c.2279_2280dup p.N761* | Frame Shift Ins (INS) | VAF 128/326 reads (39%) | called by mutect2, varscan2
- SFMBT2 | c.1897_1902del p.L633_E634del | In Frame Del (DEL) | VAF 21/69 reads (30%) | called by mutect2, pindel, varscan2
- SMAD4 | c.692del p.G231Afs*10 | Frame Shift Del (DEL) | VAF 46/71 reads (65%) | called by mutect2, pindel, varscan2
- SMC1B | c.972del p.K324Nfs*10 | Frame Shift Del (DEL) | VAF 89/284 reads (31%) | called by mutect2, pindel, varscan2
- SMTNL1 | c.1097_1099del p.F366del (on ENST00000399154; = p.F403del on NM_001105565.2) | In Frame Del (DEL) | VAF 12/29 reads (41%) | called by mutect2, pindel, varscan2
- SREK1IP1 | c.407dup p.K137Efs*12 | Frame Shift Ins (INS) | VAF 52/132 reads (39%) | called by mutect2, varscan2
- TAF4 | c.2664del p.K888Nfs*4 | Frame Shift Del (DEL) | VAF 22/138 reads (16%) | called by mutect2, varscan2
- TAP2 | c.223del p.L75* | Frame Shift Del (DEL) | VAF 14/23 reads (61%) | called by mutect2, pindel, varscan2
- TBK1 | c.1972_1973del p.L658Afs*23 | Frame Shift Del (DEL) | VAF 28/63 reads (44%) | called by pindel, varscan2
- TCERG1 | c.2947dup p.I983Nfs*3 | Frame Shift Ins (INS) | VAF 23/64 reads (36%) | called by mutect2, varscan2
- TM9SF4 | c.1275del p.F425Lfs*7 | Frame Shift Del (DEL) | VAF 33/88 reads (38%) | called by mutect2, pindel, varscan2
- TMEM131 | c.4404dup p.L1469Tfs*5 | Frame Shift Ins (INS) | VAF 134/389 reads (34%) | called by mutect2, pindel, varscan2
- TNFSF18 | c.548del p.N183Ifs*10 | Frame Shift Del (DEL) | VAF 22/156 reads (14%) | called by mutect2, varscan2
- TTBK2 | c.2627dup p.N876Kfs*2 | Frame Shift Ins (INS) | VAF 51/117 reads (44%) | called by mutect2, varscan2
- UNC13C | c.4575del p.F1525Lfs*3 | Frame Shift Del (DEL) | VAF 72/183 reads (39%) | called by mutect2, pindel, varscan2
- UNC5A | c.1901del p.G634Dfs*3 | Frame Shift Del (DEL) | VAF 8/29 reads (28%) | called by mutect2, pindel, varscan2
- VCPIP1 | c.1377del p.A460Qfs*2 | Frame Shift Del (DEL) | VAF 29/95 reads (31%) | called by mutect2, pindel, varscan2
- WDR5 | c.648del p.V217Cfs*4 | Frame Shift Del (DEL) | VAF 29/69 reads (42%) | called by mutect2, pindel, varscan2
- WDR73 | c.143del p.K48Rfs*7 | Frame Shift Del (DEL) | VAF 25/233 reads (11%) | called by mutect2, pindel, varscan2
- WNT10A | c.227_228dup p.R77Cfs*79 | Frame Shift Ins (INS) | VAF 12/32 reads (38%) | called by mutect2, varscan2
- XYLT1 | c.2169del p.V724Sfs*55 | Frame Shift Del (DEL) | VAF 10/34 reads (29%) | called by mutect2, pindel, varscan2
- ZCCHC2 | c.3506del p.P1169Lfs*70 | Frame Shift Del (DEL) | VAF 69/192 reads (36%) | called by mutect2, varscan2
- ZFYVE26 | c.1220_1223delinsGAT p.D407Gfs*83 | Frame Shift Del (DEL) | VAF 5/48 reads (10%) | called by pindel, varscan2*
- ZNF398 | c.1536dup p.C513Lfs*3 (on ENST00000475153 / NM_170686.3; = p.C342Lfs*3 on NM_020781.4) | Frame Shift Ins (INS) | VAF 8/28 reads (29%) | called by mutect2, pindel, varscan2
- ZNF570 | c.474del p.F158Lfs*25 | Frame Shift Del (DEL) | VAF 21/45 reads (47%) | called by mutect2, pindel, varscan2
- ZNHIT6 | c.574_577del p.E192Sfs*7 | Frame Shift Del (DEL) | VAF 54/166 reads (33%) | called by pindel, varscan2
- ZSCAN20 | c.734dup p.G246Rfs*19 | Frame Shift Ins (INS) | VAF 7/23 reads (30%) | called by mutect2, pindel, varscan2
- AATK | c.3411C>T p.G1137= (on ENST00000326724 / NM_001080395.3; = p.G1034= on NM_004920.2) | Silent (SNP) | VAF 11/27 reads (41%) | catalogued as COSV58373764; called by muse, mutect2, varscan2
- ABCA3 | c.3504C>T p.D1168= | Silent (SNP) | VAF 18/43 reads (42%) | catalogued as rs141725577; called by muse, mutect2, varscan2
- ACAP3 | c.1197C>T p.G399= | Silent (SNP) | VAF 16/30 reads (53%) | catalogued as rs765624546, COSV57644960; called by muse, mutect2, varscan2
- ADAM29 | c.1758C>T p.Y586= | Silent (SNP) | VAF 12/34 reads (35%) | catalogued as COSV63666347; called by muse, mutect2, varscan2
- ADAMTS17 | c.1095T>C p.G365= | Silent (SNP) | VAF 22/46 reads (48%) | catalogued as COSV51495161; called by muse, mutect2
- ANK3 | c.8427G>A p.V2809= | Silent (SNP) | VAF 10/96 reads (10%) | catalogued as COSV55077812; called by muse, mutect2
197 further variants in this file (0 protein-altering or splice-affecting, 189 silent, 8 other) are not listed here.
